Somatic mutation profile of tumor specimen CDDP-A8B6-TTP1-C (aliquot CDDP-A8B6-TTP1-C-1-0-D-A500-36) from CDDP_EAGLE case CDDP-A8B6, project CDDP_EAGLE-1: CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 74 years.
Specimen CDDP-A8B6-TTP1-C: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b9d41304-116a-4508-969c-afb12718390b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen CDDP-A8B6-NB1-A (Blood Derived Normal), aliquot CDDP-A8B6-NB1-A-1-0-D-A500-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e8334fe1-edc3-49e6-966b-35e9a9ae2d0e

The open-access MAF lists 1,934 somatic variants for this specimen: 1,298 protein-altering or splice-affecting, 390 silent, 246 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,117, Silent 390, Intron 116, Nonsense Mutation 116, RNA 39, 5'UTR 30, 3'UTR 29, Frame Shift Del 24, Splice Site 19, 5'Flank 18, Splice Region 14, 3'Flank 13.

Variants (750 of 1,934; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C3orf70 | c.17C>T p.S6L | Missense Mutation (SNP) | VAF 18/82 reads (22%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as rs757159118, COSV58586480, COSV58587413, COSV58588338; called by muse, varscan2
- MYBPC3 | c.2827C>T p.R943* | Nonsense Mutation (SNP) | VAF 14/65 reads (22%) | catalogued as rs387907267, CM032959, COSV57023485, COSV99920190; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A1BG | c.221C>T p.S74L | Missense Mutation (SNP) | VAF 46/158 reads (29%) | SIFT tolerated (0.49); PolyPhen benign (0.043); catalogued as rs771377885, COSV54049921; called by muse, mutect2, varscan2
- ABCC1 | c.1363C>G p.L455V | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.9); catalogued as COSV60680943, COSV60694471; called by muse, mutect2, varscan2
- ABCD2 | c.758C>A p.P253Q | Missense Mutation (SNP) | VAF 72/145 reads (50%) | SIFT tolerated (0.3); PolyPhen benign (0.433); catalogued as rs376662929; called by muse, mutect2, varscan2
- ABHD16B | c.614C>A p.P205H | Missense Mutation (SNP) | VAF 60/218 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748990443, COSV53861559; called by muse, mutect2, varscan2
- ABTB2 | c.1807G>A p.E603K | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.687); catalogued as rs377260183; called by muse, mutect2, varscan2
- ACAD11 | c.1820G>T p.R607L | Missense Mutation (SNP) | VAF 30/157 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV53893892; called by muse, mutect2, varscan2
- ACKR1 | c.290C>A p.P97H | Missense Mutation (SNP) | VAF 89/182 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV63671841, COSV63673628; called by muse, mutect2, varscan2
- ACSL4 | c.2067C>G p.F689L (on ENST00000340800 / NM_022977.2; = p.F648L on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 59/146 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.125); catalogued as COSV61613391; called by muse, mutect2, varscan2
- ACTB | c.695C>G p.S232C | Missense Mutation (SNP) | VAF 102/488 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as COSV59316808; called by muse, mutect2, varscan2
- ACTL6B | c.1166G>T p.S389I | Missense Mutation (SNP) | VAF 93/195 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.958); catalogued as COSV50513924; called by muse, mutect2, varscan2
- ACTN2 | c.1429G>T p.V477L | Missense Mutation (SNP) | VAF 119/276 reads (43%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV63972271; called by muse, mutect2, varscan2
- ADAMTS12 | c.4373C>A p.T1458K | Missense Mutation (SNP) | VAF 25/124 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs76061577; called by muse, mutect2, varscan2
- ADAMTS12 | c.4163A>T p.E1388V | Missense Mutation (SNP) | VAF 41/89 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV61256274, COSV61262093; called by muse, mutect2, varscan2
- ADAMTS19 | c.2110C>A p.Q704K | Missense Mutation (SNP) | VAF 68/121 reads (56%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.769); catalogued as rs374218219; called by muse, mutect2, varscan2
- ADAMTS2 | c.1307C>G p.A436G | Missense Mutation (SNP) | VAF 70/186 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV51072328; called by muse, mutect2, varscan2
- ADAMTS20 | c.2603G>A p.R868Q | Missense Mutation (SNP) | VAF 42/80 reads (53%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.852); catalogued as rs769461598, COSV67126851; called by muse, mutect2, varscan2
- ADAMTS20 | c.1679G>T p.G560V | Missense Mutation (SNP) | VAF 34/182 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67126863, COSV67132712; called by muse, mutect2, varscan2
- ADAMTS5 | c.1782T>G p.C594W | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53176023; called by muse, mutect2, varscan2
- ADCY1 | c.3197G>T p.R1066M | Missense Mutation (SNP) | VAF 109/337 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.049); catalogued as COSV52030637; called by muse, mutect2, varscan2
- ADCY5 | c.2180G>A p.R727K | Missense Mutation (SNP) | VAF 55/171 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as COSV59194603; called by muse, mutect2, varscan2
- ADCY6 | c.1487C>A p.S496Y | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57166374; called by muse, mutect2, varscan2
- ADGRA2 | c.3724C>A p.L1242M | Missense Mutation (SNP) | VAF 105/138 reads (76%) | SIFT tolerated (0.12); PolyPhen benign (0.135); catalogued as COSV55102774; called by muse, mutect2, varscan2
- ADGRB2 | c.2824G>T p.V942L | Missense Mutation (SNP) | VAF 48/108 reads (44%) | SIFT tolerated (0.23); PolyPhen benign (0.313); catalogued as COSV57070887; called by muse, mutect2, varscan2
- ADGRB3 | c.616G>A p.G206R | Missense Mutation (SNP) | VAF 23/177 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0.013); catalogued as rs752408837, COSV65384231; called by muse, mutect2, varscan2
- ADGRB3 | c.1135G>A p.G379R | Missense Mutation (SNP) | VAF 46/197 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV65384238; called by muse, mutect2, varscan2
- ADGRB3 | c.4150G>T p.V1384L | Missense Mutation (SNP) | VAF 47/193 reads (24%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.501); catalogued as COSV53235665; called by muse, mutect2, varscan2
- ADGRE2 | c.1246G>A p.E416K | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT tolerated (0.28); PolyPhen benign (0.009); catalogued as COSV59691857, COSV59695880; called by muse, mutect2, varscan2
- ADGRF3 | c.1371G>C p.K457N (on ENST00000311519 / NM_001145168.1; = p.K258N on NM_153835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/152 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV61048899; called by muse, mutect2, varscan2
- ADGRF3 | c.123G>C p.Q41H | Missense Mutation (SNP) | VAF 32/119 reads (27%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.135); catalogued as COSV61048909; called by muse, mutect2, varscan2
- ADGRF4 | c.979G>A p.E327K | Missense Mutation (SNP) | VAF 37/175 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as COSV51949825; called by muse, mutect2, varscan2
- ADGRG4 | c.5573C>T p.S1858F | Missense Mutation (SNP) | VAF 41/57 reads (72%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.829); catalogued as COSV54950324; called by muse, mutect2, varscan2
- ADGRL3 | c.929C>G p.A310G (on ENST00000506720 / NM_001322402.2; = p.A242G on NM_015236.6) | Missense Mutation (SNP) | VAF 87/299 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV72266109; called by muse, mutect2, varscan2
- ADGRL4 | c.484T>C p.Y162H | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.238); catalogued as COSV66059546; called by muse, mutect2, varscan2
- ADGRV1 | c.6824C>T p.T2275I | Missense Mutation (SNP) | VAF 117/189 reads (62%) | SIFT deleterious (0.04); PolyPhen benign (0.288); catalogued as COSV67978165; called by muse, mutect2, varscan2
- ADO | c.301T>C p.F101L | Missense Mutation (SNP) | VAF 35/129 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV65677695; called by muse, mutect2, varscan2
- AFF3 | c.1732C>A p.P578T | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.38); PolyPhen benign (0.067); catalogued as COSV104396104, COSV57841791; called by muse, mutect2, varscan2
- AGL | c.1867G>T p.D623Y | Missense Mutation (SNP) | VAF 67/242 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54048508, COSV99649244; called by muse, mutect2, varscan2
- AHNAK | c.9407C>A p.A3136D | Missense Mutation (SNP) | VAF 80/408 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.439); catalogued as COSV57204647; called by muse, mutect2, varscan2
- AIFM3 | c.449G>T p.S150I | Missense Mutation (SNP) | VAF 67/98 reads (68%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as COSV58997549; called by muse, mutect2, varscan2
- AKAP11 | c.2321C>T p.S774F | Missense Mutation (SNP) | VAF 57/113 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV50292906; called by muse, mutect2, varscan2
- AKAP11 | c.3991C>G p.L1331V | Missense Mutation (SNP) | VAF 45/96 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV50292919, COSV50300543; called by muse, mutect2, varscan2
- AKIP1 | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 23/174 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.178); catalogued as COSV100214980, COSV55148552; called by muse, mutect2
- AL031777.2 | c.97C>A p.R33S | Missense Mutation (SNP) | VAF 35/118 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.716); catalogued as rs374147454; called by muse, mutect2, varscan2
- ALAS2 | c.733G>C p.E245Q | Missense Mutation (SNP) | VAF 43/161 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.009); catalogued as COSV58188619, COSV58189035; called by muse, mutect2, varscan2
- ALDH1B1 | c.272C>T p.S91F | Missense Mutation (SNP) | VAF 21/138 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as COSV66619298; called by muse, mutect2, varscan2
- ALMS1 | c.1769C>A p.P590Q | Missense Mutation (SNP) | VAF 39/184 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV52503570; called by muse, mutect2, varscan2
- ALMS1 | c.2156G>C p.R719T | Missense Mutation (SNP) | VAF 108/400 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.177); catalogued as CD150695, COSV52503583; called by muse, mutect2, varscan2
- AMELX | c.346C>A p.Q116K | Missense Mutation (SNP) | VAF 258/329 reads (78%) | SIFT deleterious (0.02); PolyPhen benign (0.237); catalogued as COSV61624428; called by muse, mutect2, varscan2
- AMOTL1 | c.140G>T p.G47V | Missense Mutation (SNP) | VAF 34/143 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.784); catalogued as COSV54414331; called by muse, mutect2, varscan2
- ANGPT1 | c.865G>T p.V289L | Missense Mutation (SNP) | VAF 66/96 reads (69%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as COSV52431777; called by muse, mutect2, varscan2
- ANK3 | c.9640A>T p.K3214* | Nonsense Mutation (SNP) | VAF 78/197 reads (40%) | catalogued as COSV55045541; called by muse, mutect2, varscan2
- ANKFY1 | c.3401G>T p.C1134F (on ENST00000341657 / NM_001330063.2; = p.C1135F on NM_016376.5) | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58914808; called by muse, mutect2, varscan2
- ANKRD26 | c.692C>G p.S231C | Missense Mutation (SNP) | VAF 36/153 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.873); catalogued as COSV63091812; called by muse, mutect2, varscan2
- ANKRD30B | c.34G>A p.V12M | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.791); catalogued as rs1265221333, COSV62811336; called by muse, mutect2, varscan2
- ANKRD30B | c.1456G>T p.D486Y | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.557); catalogued as COSV62811347; called by muse, varscan2
- ANKRD30B | c.3427C>A p.Q1143K | Missense Mutation (SNP) | VAF 30/116 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.261); catalogued as COSV100271414; called by muse, mutect2, varscan2
- ANO10 | c.719A>C p.Y240S | Missense Mutation (SNP) | VAF 70/190 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.069); catalogued as COSV52728703; called by muse, mutect2, varscan2
- ANO9 | c.889G>T p.D297Y | Missense Mutation (SNP) | VAF 79/184 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV60448130, COSV60448376; called by muse, mutect2, varscan2
- ANP32B | c.655G>C p.D219H | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as COSV59586117; called by muse, mutect2, varscan2
- AP2M1 | c.478G>T p.G160C | Missense Mutation (SNP) | VAF 58/471 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV53047157; called by muse, mutect2, varscan2
- APBA2 | c.742G>C p.A248P | Missense Mutation (SNP) | VAF 110/200 reads (55%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.261); catalogued as COSV101382619, COSV68788998; called by muse, mutect2, varscan2
- APBA3 | c.38C>T p.P13L | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as COSV57462180; called by muse, varscan2
- APBB1IP | c.844G>T p.E282* | Nonsense Mutation (SNP) | VAF 11/41 reads (27%) | catalogued as COSV66130623, COSV66130669, COSV66130705; called by muse, mutect2, varscan2
- APCDD1 | c.312G>T p.K104N | Missense Mutation (SNP) | VAF 47/181 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.457); catalogued as COSV62372072; called by muse, mutect2, varscan2
- APLF | c.1237G>C p.D413H | Missense Mutation (SNP) | VAF 35/166 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.62); catalogued as COSV58142758; called by muse, mutect2, varscan2
- APOA2 | c.203C>T p.S68L | Missense Mutation (SNP) | VAF 39/184 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.06); catalogued as COSV57154184; called by muse, mutect2, varscan2
- ARFGEF1 | c.2503A>G p.T835A | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51603062; called by muse, mutect2, varscan2
- ARFRP1 | c.346G>C p.E116Q | Missense Mutation (SNP) | VAF 49/101 reads (49%) | SIFT tolerated (0.12); PolyPhen benign (0.291); catalogued as COSV53926437; called by muse, mutect2, varscan2
- ARG2 | c.738C>G p.I246M | Missense Mutation (SNP) | VAF 67/115 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV53619126; called by muse, mutect2, varscan2
- ARHGAP21 | c.3213G>T p.L1071F | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.913); catalogued as COSV57602608; called by muse, mutect2, varscan2
- ARHGAP22 | c.1535G>T p.W512L | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.784); catalogued as COSV50933067; called by muse, mutect2, varscan2
- ARHGEF10L | c.2770C>G p.L924V | Missense Mutation (SNP) | VAF 46/88 reads (52%) | SIFT tolerated (0.27); PolyPhen benign (0.087); catalogued as COSV51428543; called by muse, mutect2, varscan2
- ARHGEF12 | c.3509C>T p.S1170L | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.058); catalogued as COSV63102858, COSV63107870; called by muse, mutect2, varscan2
- ARHGEF7 | c.1272G>T p.M424I (on ENST00000375741 / NM_001113511.2; = p.M246I on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 106/142 reads (75%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.779); catalogued as COSV54539261; called by muse, mutect2, varscan2
- ARMC4 | c.3113C>T p.T1038I | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV59456878; called by muse, mutect2, varscan2
- ARMC4 | c.3016G>T p.V1006L | Missense Mutation (SNP) | VAF 35/149 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV59456908; called by muse, mutect2
- ARMCX2 | c.271G>C p.D91H | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.12); catalogued as rs377068571, COSV57529282, COSV57529351; called by muse, mutect2, varscan2
- ARSF | c.50T>A p.L17* | Nonsense Mutation (SNP) | VAF 49/149 reads (33%) | catalogued as COSV63839035; called by muse, mutect2, varscan2
- ARX | c.757G>C p.E253Q | Missense Mutation (SNP) | VAF 61/346 reads (18%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.007); catalogued as COSV66874833; called by muse, mutect2, varscan2
- ASAP1 | c.2987G>C p.G996A | Missense Mutation (SNP) | VAF 62/243 reads (26%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV63044819, COSV63044962; called by muse, mutect2, varscan2
- ASCC3 | c.1862G>T p.G621V | Missense Mutation (SNP) | VAF 75/275 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61226011; called by muse, mutect2, varscan2
- ASGR1 | c.428C>T p.A143V | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT tolerated (0.51); PolyPhen benign (0.01); catalogued as rs1340268632, COSV52648428; called by muse, mutect2, varscan2
- ASIC1 | c.388G>T p.A130S | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.276); catalogued as COSV57316280; called by muse, varscan2
- ATG101 | c.88C>G p.L30V | Missense Mutation (SNP) | VAF 36/169 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.704); catalogued as COSV61084911, COSV61085560; called by muse, mutect2, varscan2
- ATP2B2 | c.3221C>A p.P1074Q (on ENST00000352432; = p.P1040Q on NM_001683.5) | Missense Mutation (SNP) | VAF 40/267 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59490169; called by muse, varscan2
- ATP2B2 | c.3220C>G p.P1074A (on ENST00000352432; = p.P1040A on NM_001683.5) | Missense Mutation (SNP) | VAF 42/271 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV59490184; called by muse, mutect2, varscan2
- ATP2B2 | c.1780G>C p.V594L (on ENST00000352432; = p.V560L on NM_001683.5) | Missense Mutation (SNP) | VAF 119/257 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.387); catalogued as COSV100660611, COSV59487900, COSV59490206; called by muse, mutect2, varscan2
- ATP6AP2 | c.517C>G p.L173V | Missense Mutation (SNP) | VAF 16/392 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV65797208; called by muse, mutect2
- ATP9A | c.1447G>A p.E483K | Missense Mutation (SNP) | VAF 61/244 reads (25%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.811); catalogued as COSV58770460; called by muse, mutect2, varscan2
- ATP9B | c.1289T>A p.M430K | Missense Mutation (SNP) | VAF 54/216 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV56946590; called by muse, mutect2, varscan2
- ATXN2L | c.967G>T p.E323* | Nonsense Mutation (SNP) | VAF 20/71 reads (28%) | catalogued as COSV57365771; called by muse, mutect2, varscan2
- AUTS2 | c.3010G>C p.E1004Q | Missense Mutation (SNP) | VAF 108/153 reads (71%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.743); catalogued as COSV61381410, COSV61384946, COSV99048186; called by muse, mutect2, varscan2
- B3GALT1 | c.209C>A p.P70H | Missense Mutation (SNP) | VAF 28/176 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as COSV59908098; called by muse, mutect2, varscan2
- B3GALT2 | c.619G>C p.E207Q | Missense Mutation (SNP) | VAF 38/163 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.1); catalogued as COSV66463852; called by muse, mutect2, varscan2
- B3GNT6 | c.574G>C p.D192H | Missense Mutation (SNP) | VAF 45/133 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV62827892; called by muse, mutect2, varscan2
- B4GALNT4 | c.2654T>A p.L885Q | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV57321762; called by muse, mutect2, varscan2
- BACH1 | c.1787A>C p.K596T | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV54517428, COSV54520210; called by muse, varscan2
- BACH2 | c.144C>G p.F48L | Missense Mutation (SNP) | VAF 60/272 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.455); catalogued as COSV57585118; called by muse, varscan2
- BARHL2 | c.875C>A p.A292E | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV64980851, COSV64981591; called by muse, mutect2, varscan2
- BBS5 | c.268G>T p.G90C | Missense Mutation (SNP) | VAF 105/234 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54752009; called by muse, mutect2, varscan2
- BCAM | c.389G>T p.G130V | Missense Mutation (SNP) | VAF 51/113 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54300675; called by muse, mutect2, varscan2
- BCDIN3D | c.293C>T p.S98L | Missense Mutation (SNP) | VAF 45/136 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV61702228; called by muse, mutect2, varscan2
- BCL11B | c.1422G>A p.M474I (on ENST00000357195 / NM_001282237.2; = p.M403I on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 164/331 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV61733610; called by muse, mutect2, varscan2
- BCL7A | c.232C>T p.P78S | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); catalogued as COSV55846694, COSV55847490; called by muse, mutect2, varscan2
- BDKRB2 | c.1042C>T p.Q348* | Nonsense Mutation (SNP) | VAF 79/105 reads (75%) | catalogued as COSV60013727; called by muse, mutect2, varscan2
- BIRC2 | c.682A>T p.S228C | Missense Mutation (SNP) | VAF 37/128 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); catalogued as COSV57160665; called by muse, mutect2, varscan2
- BIRC3 | c.966G>C p.L322F | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV54815199, COSV54819135; called by muse, mutect2, varscan2
- BIRC6 | c.10882G>T p.D3628Y | Missense Mutation (SNP) | VAF 96/391 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV70195470, COSV70195838; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.1614G>C p.K538N | Missense Mutation (SNP) | VAF 111/278 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63243969; called by muse, mutect2, varscan2
- BMPER | c.1196C>T p.S399L | Missense Mutation (SNP) | VAF 84/486 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.102); catalogued as rs1252694483, COSV51811898; called by muse, mutect2, varscan2
- BMPR1B | c.875A>G p.K292R | Missense Mutation (SNP) | VAF 75/119 reads (63%) | SIFT tolerated (0.12); PolyPhen benign (0.125); catalogued as rs1001539320, COSV52775015; called by muse, mutect2, varscan2
- BNC2 | c.1777C>T p.P593S | Missense Mutation (SNP) | VAF 48/269 reads (18%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.994); catalogued as COSV66141165; called by muse, mutect2, varscan2
- BNC2 | c.1303G>T p.A435S | Missense Mutation (SNP) | VAF 118/349 reads (34%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV66141175; called by muse, mutect2, varscan2
- BPIFB2 | c.974T>A p.V325E | Missense Mutation (SNP) | VAF 29/151 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.398); catalogued as COSV50063183; called by muse, mutect2, varscan2
- BPIFB3 | c.1281G>T p.W427C | Missense Mutation (SNP) | VAF 115/976 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64956866; called by muse, mutect2, varscan2
- BPIFB4 | c.1189G>T p.G397W | Missense Mutation (SNP) | VAF 57/444 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs544445188, COSV64950731, COSV64950852; called by muse, mutect2, varscan2
- BRD9 | c.18G>C p.K6N | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV51319287; called by muse, mutect2
- BRSK1 | c.517G>T p.A173S | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV58664839; called by muse, mutect2, varscan2
- BRSK2 | c.1802C>T p.A601V | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.046); catalogued as rs750326699, COSV57540362; called by muse, mutect2, varscan2
- BRWD1 | c.3926G>C p.R1309T | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as COSV60893044; called by muse, mutect2, varscan2
- BTK | c.1486C>G p.Q496E | Missense Mutation (SNP) | VAF 11/324 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as CM066744, COSV58117599; called by muse, mutect2
- BTN2A2 | c.1052G>A p.R351Q | Missense Mutation (SNP) | VAF 46/178 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.157); catalogued as rs748274583, COSV61856668; called by muse, mutect2, varscan2
- C19orf44 | c.638G>A p.S213N | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55610287; called by muse, mutect2, varscan2
- C19orf73 | c.295C>T p.Q99* | Nonsense Mutation (SNP) | VAF 32/122 reads (26%) | catalogued as COSV55521088; called by muse, mutect2, varscan2
- C2orf78 | c.1955C>A p.S652Y | Missense Mutation (SNP) | VAF 37/145 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68516431, COSV68518637; called by muse, mutect2, varscan2
- C3orf14 | c.235G>C p.E79Q | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.892); catalogued as COSV51706355; called by muse, mutect2, varscan2
- C5orf15 | c.313C>A p.H105N | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.035); catalogued as COSV51548002; called by muse, mutect2, varscan2
- C6orf163 | c.718G>T p.E240* | Nonsense Mutation (SNP) | VAF 60/275 reads (22%) | catalogued as COSV65825011; called by muse, mutect2, varscan2
- C7 | c.1731G>C p.L577F | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57471257; called by muse, mutect2, varscan2
- CA5A | c.779C>G p.S260C | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.797); catalogued as COSV59241329; called by muse, mutect2, varscan2
- CACNA2D1 | c.158G>T p.G53V | Missense Mutation (SNP) | VAF 69/319 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.547); catalogued as COSV62373469, COSV62394715; called by muse, mutect2, varscan2
- CARD11 | c.2893C>A p.L965M | Missense Mutation (SNP) | VAF 43/127 reads (34%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.959); catalogued as COSV67797104; called by muse, mutect2, varscan2
- CARNMT1 | c.148G>A p.A50T | Missense Mutation (SNP) | VAF 76/249 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as COSV65190116; called by muse, varscan2
- CASKIN1 | c.2747G>T p.R916L | Missense Mutation (SNP) | VAF 62/106 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV58212889, COSV58213260; called by muse, mutect2, varscan2
- CASKIN1 | c.2746C>G p.R916G | Missense Mutation (SNP) | VAF 61/104 reads (59%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as rs763620122, COSV58212892; called by muse, mutect2, varscan2
- CASP9 | c.55G>C p.E19Q | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.841); catalogued as COSV61600925; called by muse, mutect2, varscan2
- CATSPERG | c.2896G>A p.D966N | Missense Mutation (SNP) | VAF 276/373 reads (74%) | SIFT deleterious (0.01); PolyPhen benign (0.154); catalogued as COSV53046156; called by muse, mutect2, varscan2
- CBL | c.2629G>T p.A877S | Missense Mutation (SNP) | VAF 91/320 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.851); catalogued as COSV50630351; called by muse, mutect2, varscan2
- CC2D2A | c.2411G>A p.S804N | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.928); catalogued as COSV67502350, COSV67506055; called by muse, mutect2, varscan2
- CCDC172 | c.144G>C p.E48D | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.52); catalogued as COSV60936745; called by muse, mutect2, varscan2
- CCDC175 | c.411G>T p.M137I | Missense Mutation (SNP) | VAF 28/45 reads (62%) | SIFT tolerated (0.29); PolyPhen benign (0.038); catalogued as rs1014431560, COSV55787326; called by muse, mutect2, varscan2
- CCDC178 | c.1120G>A p.E374K | Missense Mutation (SNP) | VAF 36/73 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.119); catalogued as COSV55760721; called by muse, mutect2, varscan2
- CCDC22 | c.360A>T p.A120= | Splice Region (SNP) | VAF 77/179 reads (43%) | catalogued as COSV66109151; called by muse, mutect2, varscan2
- CCDC78 | c.1030G>A p.D344N | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.32); PolyPhen benign (0.241); catalogued as COSV53495012; called by muse, mutect2, varscan2
- CCKAR | c.268C>T p.L90F | Missense Mutation (SNP) | VAF 81/214 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV55160157; called by muse, mutect2, varscan2
- CCM2L | c.946G>T p.E316* | Nonsense Mutation (SNP) | VAF 26/342 reads (8%) | catalogued as COSV52949176; called by muse, mutect2
- CCN1 | c.617C>T p.S206L | Missense Mutation (SNP) | VAF 37/150 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV71704280; called by muse, mutect2, varscan2
- CCNG2 | c.581G>A p.C194Y | Missense Mutation (SNP) | VAF 55/105 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV60353160; called by muse, mutect2, varscan2
- CD109 | c.2878G>T p.G960C | Missense Mutation (SNP) | VAF 33/61 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54645748; called by muse, mutect2, varscan2
- CD33 | c.618C>A p.H206Q | Missense Mutation (SNP) | VAF 63/194 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV51800122; called by muse, mutect2, varscan2
- CD6 | c.1924G>A p.E642K | Missense Mutation (SNP) | VAF 26/704 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as COSV57842661; called by muse, mutect2
- CD74 | c.28C>T p.R10W | Missense Mutation (SNP) | VAF 47/243 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs776339297, COSV50532121; called by muse, mutect2, varscan2
- CDH12 | c.503C>T p.T168I | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.068); catalogued as rs762216954; called by muse, varscan2
- CDH2 | c.347A>T p.Q116L | Missense Mutation (SNP) | VAF 80/286 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV52272624; called by muse, mutect2, varscan2
- CDH23 | c.9757G>C p.D3253H | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.729); catalogued as COSV56449624; called by muse, mutect2, varscan2
- CDH4 | c.1947C>G p.F649L | Missense Mutation (SNP) | VAF 69/325 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV64642995, COSV64674192; called by muse, mutect2, varscan2
- CDH7 | c.1978G>A p.E660K | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59881976; called by muse, mutect2, varscan2
- CDH9 | c.1284C>A p.D428E | Missense Mutation (SNP) | VAF 29/174 reads (17%) | SIFT tolerated (0.87); PolyPhen benign (0.074); catalogued as COSV50253576; called by muse, mutect2, varscan2
- CDK5RAP3 | c.855C>G p.I285M | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.255); catalogued as COSV58114296; called by muse, mutect2, varscan2
- CEACAM3 | c.584C>A p.A195D | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.323); catalogued as rs1555827349, COSV55760859; called by muse, mutect2, varscan2
- CEBPA | c.886G>C p.V296L | Missense Mutation (SNP) | VAF 96/1167 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57196081; called by muse, mutect2
- CECR2 | c.2684G>C p.G895A (on ENST00000342247 / NM_001290047.2; = p.G712A on NM_001290046.1) | Missense Mutation (SNP) | VAF 56/327 reads (17%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.138); catalogued as COSV52841645; called by muse, mutect2, varscan2
- CELSR2 | c.1579G>T p.V527F | Missense Mutation (SNP) | VAF 32/113 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV54767370; called by muse, mutect2, varscan2
- CEP152 | c.4550C>G p.S1517* (on ENST00000380950 / NM_001194998.2; = p.S1461* on NM_014985.4) | Nonsense Mutation (SNP) | VAF 79/290 reads (27%) | catalogued as COSV100358875, COSV57856925; called by muse, mutect2, varscan2
- CEP63 | c.1970C>T p.S657F | Missense Mutation (SNP) | VAF 65/354 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as rs374919528; called by muse, mutect2, varscan2
- CERS3 | c.399G>C p.Q133H | Missense Mutation (SNP) | VAF 63/142 reads (44%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.89); catalogued as COSV52565261; called by muse, varscan2
- CERS3 | c.275G>T p.R92M | Missense Mutation (SNP) | VAF 59/114 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV52565268; called by muse, mutect2, varscan2
- CETN1 | c.458G>T p.G153V | Missense Mutation (SNP) | VAF 53/105 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV59120935; called by muse, mutect2, varscan2
- CFAP44 | c.3469G>C p.D1157H | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as COSV67248708; called by muse, mutect2, varscan2
- CFAP70 | c.3217C>A p.L1073M | Missense Mutation (SNP) | VAF 78/143 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV60281160; called by muse, mutect2, varscan2
- CFAP70 | c.355A>T p.S119C | Missense Mutation (SNP) | VAF 73/287 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as COSV60281169; called by muse, mutect2, varscan2
- CFAP94 | c.148G>T p.E50* (on ENST00000320267 / NM_001352064.2; = p.E56* on NM_018272.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 34/144 reads (24%) | catalogued as rs1207570974, COSV57230215; called by muse, mutect2, varscan2
- CHD1L | c.1735G>T p.D579Y | Missense Mutation (SNP) | VAF 42/66 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63612888; called by muse, mutect2, varscan2
- CHD5 | c.1102G>T p.V368L | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV52408358, COSV99315280; called by muse, mutect2, varscan2
- CHD7 | c.8953G>C p.D2985H | Missense Mutation (SNP) | VAF 97/353 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.135); catalogued as COSV71107401; called by muse, mutect2, varscan2
- CLASP1 | c.3020G>C p.R1007T | Missense Mutation (SNP) | VAF 36/173 reads (21%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.608); catalogued as COSV55314971; called by muse, mutect2, varscan2
- CLCA2 | c.2348T>C p.L783P | Missense Mutation (SNP) | VAF 45/122 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs1256232146, COSV65286215; called by muse, mutect2, varscan2
- CLDN25 | c.520A>G p.I174V | Missense Mutation (SNP) | VAF 65/187 reads (35%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs764144573, COSV71620411; called by muse, mutect2, varscan2
- CLK4 | c.718G>C p.E240Q | Missense Mutation (SNP) | VAF 19/160 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.853); catalogued as COSV60317755; called by muse, mutect2, varscan2
- CLSPN | c.2094A>C p.E698D | Missense Mutation (SNP) | VAF 72/158 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0.012); catalogued as COSV52047228; called by muse, varscan2
- CNDP2 | c.415G>T p.G139C | Missense Mutation (SNP) | VAF 56/205 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.255); catalogued as rs747520460, COSV60839068, COSV60839124; called by muse, mutect2, varscan2
- CNTNAP1 | c.3056C>G p.S1019C | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.907); catalogued as COSV52848103; called by muse, mutect2, varscan2
- CNTRL | c.772C>A p.Q258K | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.095); catalogued as COSV53043651; called by muse, mutect2, varscan2
- COL11A1 | c.5284G>T p.G1762C | Missense Mutation (SNP) | VAF 36/113 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV62173930; called by muse, mutect2, varscan2
- COL11A1 | c.5283A>C p.K1761N | Missense Mutation (SNP) | VAF 36/112 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.011); catalogued as COSV62173940, COSV62195036; called by muse, mutect2, varscan2
- COL12A1 | c.9014C>T p.P3005L | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV59390184; called by muse, mutect2, varscan2
- COL12A1 | c.8093C>G p.S2698* | Nonsense Mutation (SNP) | VAF 17/79 reads (22%) | catalogued as COSV59390193, COSV59396610; called by muse, mutect2, varscan2
- COL13A1 | c.1582G>A p.E528K (on ENST00000398978 / NM_001130103.2; = p.E471K on NM_080798.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.987); catalogued as rs1210569417, COSV62567258; called by muse, mutect2, varscan2
- COL13A1 | c.1744C>A p.Q582K (on ENST00000398978 / NM_001130103.2; = p.Q510K on NM_080798.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT tolerated (0.66); PolyPhen probably damaging (0.949); catalogued as COSV62567272; called by muse, mutect2, varscan2
- COL20A1 | c.2885T>A p.V962E | Missense Mutation (SNP) | VAF 76/144 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.544); catalogued as COSV58912213; called by muse, mutect2, varscan2
- COL22A1 | c.3994C>G p.P1332A | Missense Mutation (SNP) | VAF 60/83 reads (72%) | SIFT tolerated (0.07); PolyPhen benign (0.266); catalogued as COSV57324910; called by muse, mutect2, varscan2
- COL4A5 | c.86G>C p.C29S | Missense Mutation (SNP) | VAF 127/178 reads (71%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); catalogued as COSV60356698; called by muse, mutect2, varscan2
- COL4A5 | c.1516G>A p.G506R | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV60356710; called by muse, varscan2
- COL6A6 | c.2294T>A p.L765H | Missense Mutation (SNP) | VAF 108/226 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100650206, COSV62018587; called by muse, mutect2, varscan2
- COL6A6 | c.3967G>C p.E1323Q | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV62018597; called by muse, mutect2, varscan2
- COL6A6 | c.5714C>T p.S1905L | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated (0.7); PolyPhen benign (0.005); catalogued as rs1343957584, COSV62018612; called by muse, varscan2
- COL7A1 | c.4366G>T p.G1456C | Missense Mutation (SNP) | VAF 67/132 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60391653; called by muse, mutect2, varscan2
- COL9A2 | c.245T>A p.I82N | Missense Mutation (SNP) | VAF 169/332 reads (51%) | SIFT tolerated (0.27); PolyPhen benign (0.123); catalogued as COSV65607127; called by muse, mutect2, varscan2
- COLGALT2 | c.121G>C p.E41Q | Missense Mutation (SNP) | VAF 82/179 reads (46%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.007); catalogued as COSV100730902, COSV62727504; called by muse, mutect2, varscan2
- COMMD2 | c.83G>T p.G28V | Missense Mutation (SNP) | VAF 38/152 reads (25%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.691); catalogued as COSV71946366; called by muse, mutect2, varscan2
- COPB1 | c.2056G>T p.E686* | Nonsense Mutation (SNP) | VAF 21/101 reads (21%) | catalogued as COSV51446865; called by muse, mutect2, varscan2
- COQ5 | c.22G>C p.A8P | Missense Mutation (SNP) | VAF 80/217 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.039); catalogued as COSV56018338; called by muse, mutect2, varscan2
- CORIN | c.3109C>G p.Q1037E | Missense Mutation (SNP) | VAF 94/179 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV56686931; called by muse, mutect2, varscan2
- CORO1C | c.1078G>A p.D360N | Missense Mutation (SNP) | VAF 7/134 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54597201; called by muse, mutect2
- CPLX2 | c.307G>T p.A103S | Missense Mutation (SNP) | VAF 50/147 reads (34%) | SIFT tolerated (0.64); PolyPhen benign (0.025); catalogued as COSV63999638; called by muse, mutect2, varscan2
- CPOX | c.53G>A p.R18Q | Missense Mutation (SNP) | VAF 26/151 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs1190003814, COSV51637519, COSV51639925; called by muse, mutect2, varscan2
- CPS1 | c.4112G>T p.R1371L | Missense Mutation (SNP) | VAF 56/272 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as CM114387, COSV51802810, COSV51802996; called by muse, mutect2, varscan2
- CPSF7 | c.1232G>A p.G411D (on ENST00000394888 / NM_001136040.4; = p.G454D on NM_024811.4) | Missense Mutation (SNP) | VAF 20/359 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.157); catalogued as COSV61210267; called by muse, mutect2
- CRACDL | c.1706G>C p.R569P | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as COSV67406662; called by muse, mutect2, varscan2
- CRADD | c.460C>T p.H154Y | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs766702926, COSV60552223; called by muse, mutect2, varscan2
- CREBBP | c.4394G>T p.G1465V | Missense Mutation (SNP) | VAF 129/186 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52114921, COSV99269794; called by muse, mutect2, varscan2
- CREBZF | c.479C>G p.S160C | Missense Mutation (SNP) | VAF 78/228 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as rs1321072084, COSV52628989, COSV99476398; called by muse, mutect2, varscan2
- CRNN | c.1115G>C p.R372T | Missense Mutation (SNP) | VAF 93/464 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.068); catalogued as rs202167285, COSV55120856; called by muse, mutect2, varscan2
- CSMD2 | c.4546T>A p.Y1516N | Missense Mutation (SNP) | VAF 83/200 reads (42%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.925); catalogued as COSV53883386; called by muse, mutect2, varscan2
- CSMD2 | c.147C>A p.Y49* | Nonsense Mutation (SNP) | VAF 102/471 reads (22%) | catalogued as rs370850896, COSV53883470; called by muse, mutect2, varscan2
- CSMD3 | c.10580G>C p.R3527T (on ENST00000297405 / NM_001363185.1; = p.R3358T on NM_052900.3) | Missense Mutation (SNP) | VAF 233/326 reads (71%) | SIFT deleterious (0.03); PolyPhen benign (0.074); catalogued as COSV52103785, COSV52109751; called by muse, mutect2, varscan2
- CTAGE1 | c.1016C>A p.T339K | Missense Mutation (SNP) | VAF 68/308 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.02); catalogued as COSV66944658; called by muse, mutect2, varscan2
- CTNND1 | c.1849A>G p.S617G | Missense Mutation (SNP) | VAF 40/125 reads (32%) | SIFT tolerated (0.88); PolyPhen benign (0.003); catalogued as rs756952348, COSV62382300; called by muse, mutect2, varscan2
- CUX2 | c.1737C>A p.Y579* | Nonsense Mutation (SNP) | VAF 38/102 reads (37%) | catalogued as COSV55625277; called by muse, mutect2, varscan2
- CXorf38 | c.391G>A p.E131K | Missense Mutation (SNP) | VAF 25/138 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as COSV59947307; called by muse, mutect2, varscan2
- CYB5R4 | c.292A>G p.R98G | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.145); catalogued as COSV63746017; called by muse, mutect2, varscan2
- CYP2B6 | c.383C>G p.S128C | Missense Mutation (SNP) | VAF 83/797 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.291); catalogued as COSV57842594; called by muse, mutect2, varscan2
- CYP3A43 | c.516G>C p.L172F | Missense Mutation (SNP) | VAF 141/193 reads (73%) | SIFT deleterious (0.01); PolyPhen benign (0.292); catalogued as COSV55935113; called by muse, mutect2, varscan2
- CYP4A22 | c.340C>A p.P114T | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as COSV53738350; called by muse, mutect2, varscan2
- CYP7B1 | c.1490A>T p.D497V | Missense Mutation (SNP) | VAF 95/141 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV59582974; called by muse, mutect2, varscan2
- DACH1 | c.1030G>A p.V344M | Missense Mutation (SNP) | VAF 65/99 reads (66%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.851); catalogued as COSV57490432; called by muse, mutect2, varscan2
- DACT1 | c.1097C>A p.P366H | Missense Mutation (SNP) | VAF 98/119 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV60019537; called by muse, mutect2, varscan2
- DAG1 | c.865C>G p.Q289E | Missense Mutation (SNP) | VAF 65/111 reads (59%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV58182795; called by muse, mutect2, varscan2
- DBF4 | c.1108G>T p.E370* | Nonsense Mutation (SNP) | VAF 24/118 reads (20%) | catalogued as COSV55995936; called by muse, varscan2
- DCAF8L2 | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 53/378 reads (14%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.068); catalogued as COSV70548273; called by muse, mutect2, varscan2
- DCHS1 | c.460G>C p.E154Q | Missense Mutation (SNP) | VAF 50/197 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55031024; called by muse, mutect2, varscan2
- DCHS2 | c.1516G>C p.E506Q | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.37); catalogued as COSV59719012; called by muse, mutect2, varscan2
- DCHS2 | c.236C>T p.P79L | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV59719029, COSV59737337; called by muse, mutect2, varscan2
- DCLRE1A | c.879C>A p.F293L | Missense Mutation (SNP) | VAF 40/126 reads (32%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV63748211; called by muse, mutect2, varscan2
- DCTN3 | c.38G>T p.R13L | Missense Mutation (SNP) | VAF 36/216 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as rs1342143559, COSV52406405; called by muse, mutect2, varscan2
- DDX1 | c.1076T>G p.L359R | Missense Mutation (SNP) | VAF 37/148 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as COSV51838185; called by muse, mutect2, varscan2
- DDX20 | c.1902A>T p.K634N | Missense Mutation (SNP) | VAF 48/147 reads (33%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.023); catalogued as rs1289546106, COSV63777961; called by muse, mutect2, varscan2
- DEFB113 | c.40G>C p.V14L | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.873); catalogued as COSV67143264; called by muse, mutect2, varscan2
- DENND5B | c.2560C>G p.Q854E | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.95); catalogued as COSV60900072; called by muse, mutect2, varscan2
- DGKB | c.2304C>A p.C768* | Nonsense Mutation (SNP) | VAF 19/152 reads (13%) | catalogued as COSV51763884; called by muse, varscan2
- DGKB | c.341G>T p.G114V | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT tolerated (0.36); PolyPhen benign (0.013); catalogued as rs1042181444, COSV51763900; called by muse, varscan2
- DGLUCY | c.1174G>A p.E392K | Missense Mutation (SNP) | VAF 28/123 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.027); catalogued as rs1023097434; called by muse, varscan2
- DHX40 | c.380G>C p.G127A | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52066128, COSV99233182; called by muse, mutect2, varscan2
- DHX40 | c.553T>A p.L185I | Missense Mutation (SNP) | VAF 43/130 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.538); catalogued as COSV52066152; called by muse, mutect2, varscan2
- DIS3L2 | c.2606A>G p.E869G | Missense Mutation (SNP) | VAF 57/115 reads (50%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.011); catalogued as COSV56048818; called by muse, mutect2, varscan2
- DLGAP3 | c.1861G>A p.E621K | Missense Mutation (SNP) | VAF 157/328 reads (48%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.819); catalogued as COSV52391734; called by muse, mutect2, varscan2
- DLGAP4 | c.803C>A p.P268Q | Missense Mutation (SNP) | VAF 139/426 reads (33%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as COSV59414773; called by muse, mutect2, varscan2
- DLL3 | c.593C>G p.S198W | Missense Mutation (SNP) | VAF 44/510 reads (9%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.487); catalogued as COSV52693503; called by muse, mutect2
- DLL3 | c.1346C>G p.S449C | Missense Mutation (SNP) | VAF 66/744 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as rs771783907, COSV52693525; called by muse, mutect2
- DMGDH | c.364G>T p.E122* | Nonsense Mutation (SNP) | VAF 66/298 reads (22%) | catalogued as COSV54860762; called by muse, mutect2, varscan2
- DMP1 | c.1280G>A p.S427N | Missense Mutation (SNP) | VAF 214/316 reads (68%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV56818704; called by muse, mutect2, varscan2
- DMXL1 | c.370C>G p.R124G | Missense Mutation (SNP) | VAF 34/130 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.211); catalogued as COSV60705476, COSV60715915; called by muse, mutect2, varscan2
- DMXL2 | c.3159G>C p.L1053F | Missense Mutation (SNP) | VAF 35/119 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV51841277; called by muse, mutect2, varscan2
- DNAAF2 | c.1180C>T p.R394C | Missense Mutation (SNP) | VAF 97/190 reads (51%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs769705567, COSV53567738; called by muse, mutect2, varscan2
- DNAH10 | c.10691C>T p.S3564F (on ENST00000409039; = p.S3503F on NM_207437.3) | Missense Mutation (SNP) | VAF 60/152 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.258); catalogued as COSV68988497; called by muse, mutect2, varscan2
- DNAH11 | c.2896G>A p.G966R | Missense Mutation (SNP) | VAF 54/161 reads (34%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.934); catalogued as COSV60941508; called by muse, mutect2, varscan2
- DNAH14 | c.5021C>T p.T1674I (on ENST00000445597; = p.T2079I on NM_001367479.1) | Missense Mutation (SNP) | VAF 62/242 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.241); catalogued as COSV70531135; called by muse, mutect2, varscan2
- DNAH2 | c.5180A>G p.Y1727C | Missense Mutation (SNP) | VAF 114/179 reads (64%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.662); catalogued as COSV66716776; called by muse, mutect2, varscan2
- DNAH6 | c.11427G>C p.L3809F | Missense Mutation (SNP) | VAF 46/182 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.021); catalogued as COSV52850582; called by muse, mutect2, varscan2
- DNAH9 | c.3650C>A p.A1217E | Missense Mutation (SNP) | VAF 46/83 reads (55%) | SIFT tolerated (0.17); PolyPhen benign (0.078); catalogued as COSV52335752; called by muse, mutect2, varscan2
- DNAJB4 | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 42/105 reads (40%) | SIFT tolerated (0.44); PolyPhen benign (0.192); catalogued as COSV66131404; called by muse, mutect2, varscan2
- DNMT3A | c.931G>T p.V311L | Missense Mutation (SNP) | VAF 34/148 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.667); catalogued as COSV53040169; called by muse, mutect2, varscan2
- DNMT3A | c.587A>G p.Y196C | Missense Mutation (SNP) | VAF 25/124 reads (20%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.984); catalogued as COSV53040191; called by muse, mutect2, varscan2
- DOCK10 | c.4453G>A p.E1485K | Missense Mutation (SNP) | VAF 48/208 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV51350078; called by muse, varscan2
- DOCK11 | c.433G>C p.E145Q | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52234162; called by muse, mutect2, varscan2
- DPY19L4 | c.1414C>T p.H472Y | Missense Mutation (SNP) | VAF 47/85 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV68962278, COSV68962549; called by muse, mutect2, varscan2
- DSC3 | c.647C>T p.S216L | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.038); catalogued as COSV64571858, COSV64573727; called by muse, mutect2, varscan2
- DSG1 | c.1090C>G p.Q364E | Missense Mutation (SNP) | VAF 52/215 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.345); catalogued as COSV57133464; called by muse, mutect2, varscan2
- DSP | c.2332C>T p.L778F | Missense Mutation (SNP) | VAF 57/320 reads (18%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.997); catalogued as rs1267584840; called by muse, mutect2, varscan2
- DST | c.18484C>T p.Q6162* (on ENST00000361203 / NM_001374722.1; = p.Q3859* on NM_015548.5) | Nonsense Mutation (SNP) | VAF 28/82 reads (34%) | catalogued as COSV54999558; called by muse, mutect2, varscan2
- DUSP29 | c.124G>T p.E42* | Nonsense Mutation (SNP) | VAF 39/145 reads (27%) | catalogued as COSV58300057; called by muse, mutect2, varscan2
- DVL1 | c.144C>G p.F48L | Missense Mutation (SNP) | VAF 52/243 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.433); catalogued as COSV58509909, COSV58511515; called by muse, mutect2, varscan2
- DYRK4 | c.1162C>G p.R388G | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50537930, COSV50540502; called by muse, mutect2, varscan2
- DYSF | c.5327C>A p.P1776Q | Missense Mutation (SNP) | VAF 92/191 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV50271534; called by muse, mutect2, varscan2
- DZIP1L | c.654G>T p.W218C | Missense Mutation (SNP) | VAF 29/241 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.747); catalogued as COSV100551752, COSV59519389; called by muse, mutect2, varscan2
- DZIP1L | c.653G>T p.W218L | Missense Mutation (SNP) | VAF 29/243 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.236); catalogued as COSV59519398; called by muse, mutect2, varscan2
- EBI3 | c.200G>T p.R67M | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV55689575; called by muse, mutect2, varscan2
- ECH1 | c.279C>A p.F93L | Missense Mutation (SNP) | VAF 63/882 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as COSV55488673; called by muse, mutect2
- EFCAB5 | c.2059C>A p.P687T | Missense Mutation (SNP) | VAF 83/233 reads (36%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs1488984690, COSV57926434; called by muse, mutect2, varscan2
- EFCAB5 | c.2446C>A p.L816M | Missense Mutation (SNP) | VAF 22/190 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as COSV57926448; called by muse, mutect2, varscan2
- EFCAB6 | c.4384G>T p.V1462F | Missense Mutation (SNP) | VAF 26/43 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53058704; called by muse, varscan2
- EFCAB7 | c.958C>A p.P320T | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.54); PolyPhen benign (0.058); catalogued as COSV60683269; called by muse, mutect2
- EGFLAM | c.2582G>C p.R861T (on ENST00000354891 / NM_001205301.2; = p.R853T on NM_152403.4) | Missense Mutation (SNP) | VAF 36/152 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.972); catalogued as COSV59292810, COSV59303467; called by muse, mutect2, varscan2
- EIF2D | c.47G>C p.G16A | Missense Mutation (SNP) | VAF 35/201 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV55112164; called by muse, mutect2, varscan2
- EIF4G2 | c.2398G>C p.E800Q | Missense Mutation (SNP) | VAF 66/317 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.225); catalogued as COSV60596247; called by muse, mutect2, varscan2
- ELAVL4 | c.1034T>G p.M345R | Missense Mutation (SNP) | VAF 49/161 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63914640; called by muse, mutect2, varscan2
- ELL | c.103C>G p.L35V | Missense Mutation (SNP) | VAF 33/207 reads (16%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.457); catalogued as COSV53211315; called by muse, mutect2, varscan2
- ELN | c.241G>A p.A81T | Missense Mutation (SNP) | VAF 23/123 reads (19%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as rs1320437218; called by muse, mutect2
- EN1 | c.134G>T p.G45V | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV54630365; called by muse, mutect2, varscan2
- EP300 | c.4333G>C p.D1445H | Missense Mutation (SNP) | VAF 44/140 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54327113, COSV54337780; called by muse, mutect2, varscan2
- EPHA5 | c.2937G>T p.M979I | Missense Mutation (SNP) | VAF 41/87 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.577); catalogued as COSV56632738; called by muse, mutect2, varscan2
- EPHA6 | c.227G>A p.C76Y | Missense Mutation (SNP) | VAF 37/140 reads (26%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.006); catalogued as COSV67560412; called by muse, mutect2, varscan2
- EPHB2 | c.1121G>T p.R374L | Missense Mutation (SNP) | VAF 40/82 reads (49%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.971); catalogued as COSV65860150; called by muse, mutect2, varscan2
- ERBB4 | c.2629G>T p.A877S | Missense Mutation (SNP) | VAF 55/235 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as COSV61463924; called by muse, mutect2, varscan2
- ERBB4 | c.1970T>A p.V657E | Missense Mutation (SNP) | VAF 57/276 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); catalogued as COSV53505115; called by muse, mutect2, varscan2
- ERICH3 | c.2969C>A p.T990K | Missense Mutation (SNP) | VAF 45/153 reads (29%) | SIFT tolerated (0.67); PolyPhen benign (0.009); catalogued as rs780074982, COSV58600014; called by muse, mutect2, varscan2
- ESPNL | c.2826G>T p.K942N | Missense Mutation (SNP) | VAF 60/229 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV58032539; called by muse, varscan2
- ETV2 | c.373G>T p.E125* | Nonsense Mutation (SNP) | VAF 54/413 reads (13%) | catalogued as COSV55837053, COSV55838447; called by muse, mutect2, varscan2
- EVI5 | c.8C>A p.T3N | Missense Mutation (SNP) | VAF 37/109 reads (34%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.245); catalogued as COSV64825678; called by muse, mutect2, varscan2
- EXOC4 | c.859G>T p.A287S | Missense Mutation (SNP) | VAF 58/206 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.068); catalogued as COSV54084852; called by muse, mutect2, varscan2
- EXOC6B | c.1562A>T p.E521V | Missense Mutation (SNP) | VAF 35/140 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55545959; called by muse, mutect2, varscan2
- EXOC8 | c.376G>T p.G126W | Missense Mutation (SNP) | VAF 128/226 reads (57%) | SIFT deleterious (0.02); PolyPhen benign (0.157); catalogued as COSV50477562; called by muse, mutect2, varscan2
- EXOSC9 | c.250C>G p.Q84E | Missense Mutation (SNP) | VAF 40/142 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.388); catalogued as COSV54664976; called by muse, mutect2, varscan2
- EXT2 | c.1107G>C p.K369N (on ENST00000343631; = p.K402N on NM_000401.3) | Missense Mutation (SNP) | VAF 43/245 reads (18%) | SIFT tolerated (0.51); PolyPhen benign (0.013); catalogued as COSV59147164; called by muse, mutect2, varscan2
- EYS | c.3194G>T p.C1065F | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.061); catalogued as rs1048317896, COSV65467700; called by muse, mutect2, varscan2
- EYS | c.1252A>T p.N418Y | Missense Mutation (SNP) | VAF 54/233 reads (23%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.768); catalogued as COSV60977406; called by muse, mutect2, varscan2
- F13A1 | c.1911C>T p.V637= | Splice Region (SNP) | VAF 100/303 reads (33%) | catalogued as COSV53553864; called by muse, mutect2, varscan2
- F5 | c.5006C>A p.S1669Y | Missense Mutation (SNP) | VAF 106/224 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63121008; called by muse, mutect2, varscan2
- FABP4 | c.329A>T p.E110V | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as COSV56268634; called by muse, mutect2, varscan2
- FAM155A | c.127G>T p.A43S | Missense Mutation (SNP) | VAF 132/189 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV65550376, COSV65591457; called by muse, varscan2
- FAM184B | c.2091C>A p.H697Q | Missense Mutation (SNP) | VAF 38/143 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as COSV53951407; called by muse, mutect2, varscan2
- FAM205A | c.871G>A p.V291M | Missense Mutation (SNP) | VAF 113/323 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV66488409; called by muse, mutect2, varscan2
- FAM217A | c.1322C>G p.P441R | Missense Mutation (SNP) | VAF 88/188 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as COSV51158991; called by muse, mutect2, varscan2
- FAM220A | c.185C>T p.S62L | Missense Mutation (SNP) | VAF 83/473 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs779799309, COSV57625836; called by muse, mutect2, varscan2
- FAM222A | c.1087C>G p.P363A | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.011); catalogued as COSV62722977, COSV62723032; called by muse, mutect2, varscan2
- FAM47A | c.1457G>T p.R486L | Missense Mutation (SNP) | VAF 33/39 reads (85%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.909); catalogued as rs1408103342, COSV100649851, COSV60494256; called by muse, varscan2
- FAM47C | c.282G>C p.K94N | Missense Mutation (SNP) | VAF 49/250 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.503); catalogued as COSV63723936, COSV63728962; called by muse, mutect2, varscan2
- FAM47E | c.961C>A p.L321M | Missense Mutation (SNP) | VAF 42/69 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV60531339; called by muse, mutect2, varscan2
- FAM71E2 | c.1024C>T p.Q342* | Nonsense Mutation (SNP) | VAF 31/103 reads (30%) | catalogued as COSV52772088; called by muse, mutect2, varscan2
- FAM83B | c.775C>T p.Q259* | Nonsense Mutation (SNP) | VAF 17/58 reads (29%) | catalogued as COSV60919609; called by muse, varscan2
- FAM83F | c.202C>G p.R68G | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.638); catalogued as COSV60999517; called by muse, mutect2, varscan2
- FAT2 | c.9418C>T p.P3140S | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as COSV55814231; called by muse, varscan2
- FAT2 | c.4616T>C p.V1539A | Missense Mutation (SNP) | VAF 112/260 reads (43%) | SIFT tolerated (0.8); PolyPhen benign (0.154); catalogued as COSV55814244; called by muse, mutect2, varscan2
- FBRSL1 | c.2558G>A p.G853E | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV55509824; called by muse, mutect2, varscan2
- FBXO11 | c.1688G>T p.G563V (on ENST00000403359 / NM_001190274.2; = p.G479V on NM_025133.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.072); catalogued as COSV57016596; called by muse, mutect2, varscan2
- FBXO42 | c.841C>T p.H281Y | Missense Mutation (SNP) | VAF 43/183 reads (23%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.503); catalogued as rs769950759, COSV65044569; called by muse, mutect2, varscan2
- FBXW11 | c.59G>C p.R20T | Missense Mutation (SNP) | VAF 71/192 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.118); catalogued as COSV51605643; called by muse, mutect2, varscan2
- FCHO2 | c.459G>C p.L153F | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.416); catalogued as COSV55106187; called by muse, mutect2, varscan2
- FCHSD2 | c.716G>A p.G239E | Missense Mutation (SNP) | VAF 38/108 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs185931366; called by muse, mutect2, varscan2
- FCRL2 | c.1362C>A p.D454E | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.044); catalogued as COSV63832781; called by muse, mutect2, varscan2
- FCRL5 | c.2195G>A p.G732D | Missense Mutation (SNP) | VAF 45/173 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV62511630; called by muse, mutect2, varscan2
- FCRL5 | c.1819C>A p.L607M | Missense Mutation (SNP) | VAF 16/125 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV62511647; called by muse, mutect2, varscan2
- FDX2 | c.193G>C p.E65Q | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.697); catalogued as rs1184197568, COSV53343885; called by muse, mutect2, varscan2
- FFAR1 | c.178C>A p.P60T | Missense Mutation (SNP) | VAF 35/383 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.247); catalogued as rs865873341, COSV50049733; called by muse, mutect2
- FGD5 | c.305G>A p.R102H | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV53237930, COSV53241412; called by muse, mutect2, varscan2
- FGD5 | c.1374del p.E460Kfs*3 | Frame Shift Del (DEL) | VAF 35/179 reads (20%) | catalogued as COSV53240393; called by mutect2, pindel, varscan2
- FGF13 | c.525A>T p.K175N | Missense Mutation (SNP) | VAF 141/188 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV59543195; called by muse, mutect2, varscan2
- FH | c.32C>G p.S11W | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs1226883651, COSV63819040, COSV63819277; called by muse, mutect2, varscan2
- FHDC1 | c.3184C>T p.R1062W | Missense Mutation (SNP) | VAF 36/138 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs768907742, COSV52597860; called by muse, mutect2, varscan2
- FIP1L1 | c.1750G>A p.E584K | Missense Mutation (SNP) | VAF 51/231 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV55782418, COSV55784090; called by muse, mutect2, varscan2
- FLG | c.9607G>A p.E3203K | Missense Mutation (SNP) | VAF 60/440 reads (14%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV64237253; called by muse, mutect2, varscan2
- FLG | c.3170C>A p.A1057E | Missense Mutation (SNP) | VAF 121/523 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.048); catalogued as COSV64237263; called by muse, mutect2, varscan2
- FLG2 | c.5357G>T p.G1786V | Missense Mutation (SNP) | VAF 69/321 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as COSV66166852; called by muse, mutect2, varscan2
- FLI1 | c.835G>T p.G279W | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1457299867, COSV55642845; called by muse, mutect2, varscan2
- FLNA | c.2704G>C p.A902P | Missense Mutation (SNP) | VAF 114/139 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV61038072; called by muse, mutect2, varscan2
- FLNC | c.4417G>T p.G1473C | Missense Mutation (SNP) | VAF 58/85 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57951107; called by muse, mutect2, varscan2
- FLNC | c.5797G>A p.D1933N | Missense Mutation (SNP) | VAF 66/181 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.029); catalogued as rs762297336, COSV57951118; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FLT4 | c.4036G>C p.E1346Q | Missense Mutation (SNP) | VAF 50/295 reads (17%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.124); catalogued as rs746834315, COSV56099447; called by muse, mutect2, varscan2
- FLT4 | c.2128G>A p.V710M | Missense Mutation (SNP) | VAF 29/173 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.017); catalogued as rs758234191, COSV56097902, COSV56099457; called by muse, mutect2, varscan2
- FMNL3 | c.240C>A p.H80Q | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.727); catalogued as COSV53298338; called by muse, mutect2, varscan2
- FOXG1 | c.79G>A p.A27T | Missense Mutation (SNP) | VAF 128/174 reads (74%) | SIFT tolerated, low confidence (0.31); PolyPhen possibly damaging (0.892); catalogued as COSV57395374; called by muse, varscan2
- FOXM1 | c.994C>G p.P332A | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV61205291; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.1807A>T p.I603L | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.596); catalogued as COSV58546492, COSV58560884; called by muse, mutect2, varscan2
- FPR1 | c.327G>T p.L109F | Missense Mutation (SNP) | VAF 65/265 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.629); catalogued as rs1165447080, COSV59051098; called by muse, mutect2, varscan2
- FRAS1 | c.2491C>T p.Q831* | Nonsense Mutation (SNP) | VAF 33/80 reads (41%) | catalogued as COSV53592249; called by muse, mutect2, varscan2
- FREM2 | c.6761G>T p.G2254V | Missense Mutation (SNP) | VAF 138/200 reads (69%) | SIFT tolerated (0.15); PolyPhen benign (0.283); catalogued as COSV54827850; called by muse, mutect2, varscan2
- FREM2 | c.8409+1G>T p.X2803_splice | Splice Site (SNP) | VAF 338/455 reads (74%) | catalogued as COSV54852061; called by muse, mutect2, varscan2
- FSHR | c.503T>A p.L168Q | Missense Mutation (SNP) | VAF 57/336 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58618176; called by muse, mutect2, varscan2
- FSIP2 | c.2665C>G p.Q889E | Missense Mutation (SNP) | VAF 39/134 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.392); catalogued as COSV58078894; called by muse, mutect2, varscan2
- FSIP2 | c.4100C>G p.S1367* | Nonsense Mutation (SNP) | VAF 29/148 reads (20%) | catalogued as COSV58078904; called by muse, mutect2, varscan2
- FUBP3 | c.146C>T p.S49L | Missense Mutation (SNP) | VAF 60/198 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.319); catalogued as COSV100156218, COSV60512985; called by muse, mutect2, varscan2
- GABPB1 | c.631G>T p.V211L | Missense Mutation (SNP) | VAF 47/131 reads (36%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as COSV55013770; called by muse, mutect2, varscan2
- GABRA2 | c.490G>T p.A164S | Missense Mutation (SNP) | VAF 36/148 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV62912241; called by muse, varscan2
- GABRA4 | c.473G>A p.G158D | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51937273; called by muse, mutect2
- GABRG1 | c.699G>T p.W233C | Missense Mutation (SNP) | VAF 35/169 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV54950390, COSV54957542; called by muse, mutect2, varscan2
- GABRQ | c.1300C>A p.P434T | Missense Mutation (SNP) | VAF 32/60 reads (53%) | SIFT tolerated (0.86); PolyPhen benign (0.011); catalogued as COSV64780976; called by muse, mutect2, varscan2
- GADD45A | c.188A>T p.E63V | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); catalogued as COSV63974714; called by muse, mutect2, varscan2
- GALNT17 | c.1659C>A p.N553K | Missense Mutation (SNP) | VAF 110/145 reads (76%) | SIFT tolerated (0.07); PolyPhen benign (0.045); catalogued as COSV61149176; called by muse, mutect2, varscan2
- GALNT18 | c.1013G>T p.R338L | Missense Mutation (SNP) | VAF 38/160 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as COSV57144529; called by muse, mutect2, varscan2
- GALT | c.174G>T p.E58D | Missense Mutation (SNP) | VAF 103/287 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.177); catalogued as COSV66592594; called by muse, mutect2, varscan2
- GANAB | c.857A>T p.Q286L | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.105); catalogued as COSV60462261; called by muse, mutect2, varscan2
- GANAB | c.50C>T p.S17F | Missense Mutation (SNP) | VAF 27/126 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as COSV60462276; called by muse, mutect2, varscan2
- GATA4 | c.1270C>A p.Q424K | Missense Mutation (SNP) | VAF 189/269 reads (70%) | SIFT deleterious (0.02); PolyPhen benign (0.083); catalogued as COSV58732479; called by muse, mutect2, varscan2
- GCC2 | c.4747G>A p.E1583K | Missense Mutation (SNP) | VAF 120/474 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1458525248; called by muse, mutect2, varscan2
- GCK | c.770G>T p.W257L | Missense Mutation (SNP) | VAF 75/167 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.79); catalogued as COSV60786087; called by muse, mutect2, varscan2
- GCOM1 | c.136G>C p.E46Q | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.198); catalogued as rs927675791, COSV51088265; called by muse, mutect2, varscan2
- GK5 | c.32G>C p.R11T | Missense Mutation (SNP) | VAF 47/166 reads (28%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.003); catalogued as COSV67485306; called by muse, mutect2, varscan2
- GLDC | c.1334C>T p.S445L | Missense Mutation (SNP) | VAF 65/425 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.259); catalogued as COSV58676725; called by muse, mutect2, varscan2
- GLI1 | c.624G>T p.Q208H | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs1409773154, COSV57358320; called by muse, mutect2, varscan2
- GLI3 | c.782C>G p.A261G | Missense Mutation (SNP) | VAF 87/514 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV67885559; called by muse, varscan2
- GLIS3 | c.191C>T p.S64L | Missense Mutation (SNP) | VAF 121/332 reads (36%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1160682513, COSV67941555; called by muse, mutect2, varscan2
- GMPPA | c.728G>T p.G243V | Missense Mutation (SNP) | VAF 74/161 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0.147); catalogued as COSV58006146; called by muse, mutect2, varscan2
- GNLY | c.313G>A p.D105N | Missense Mutation (SNP) | VAF 36/195 reads (18%) | SIFT tolerated (0.49); PolyPhen benign (0.034); catalogued as rs778844953, COSV55702895; called by muse, mutect2, varscan2
- GOLPH3 | c.151G>A p.D51N | Missense Mutation (SNP) | VAF 41/234 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs747688646, COSV54059863; called by muse, mutect2, varscan2
- GPR141 | c.615G>T p.M205I | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as COSV57731392; called by muse, mutect2, varscan2
- GPR149 | c.928C>A p.R310S | Missense Mutation (SNP) | VAF 66/183 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs560059695, COSV67665559, COSV67665931; called by muse, mutect2, varscan2
- GPR162 | c.415A>G p.M139V | Missense Mutation (SNP) | VAF 31/114 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.347); catalogued as rs782068977, COSV50589197; called by muse, mutect2, varscan2
- GPR17 | c.774G>C p.K258N | Missense Mutation (SNP) | VAF 61/283 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV55754065; called by muse, mutect2, varscan2
- GPR37 | c.975G>T p.K325N | Missense Mutation (SNP) | VAF 38/204 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.444); catalogued as COSV58255621; called by muse, mutect2, varscan2
- GPRC6A | c.1369G>A p.D457N | Missense Mutation (SNP) | VAF 42/202 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.043); catalogued as COSV59951687; called by muse, varscan2
- GPRC6A | c.440G>T p.G147V | Missense Mutation (SNP) | VAF 36/143 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.438); catalogued as rs759683225, COSV59954105; called by mutect2, varscan2
- GPRC6A | c.439G>T p.G147W | Missense Mutation (SNP) | VAF 35/141 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV100114266; called by mutect2, varscan2
- GPRIN1 | c.2240G>A p.R747H | Missense Mutation (SNP) | VAF 29/105 reads (28%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs1445549801, COSV56134983; called by muse, mutect2, varscan2
- GRAMD2A | c.772G>A p.E258K | Missense Mutation (SNP) | VAF 42/162 reads (26%) | SIFT tolerated (0.42); PolyPhen benign (0.018); catalogued as COSV59032743; called by muse, mutect2
- GRIA1 | c.2106G>T p.E702D | Missense Mutation (SNP) | VAF 114/307 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.253); catalogued as COSV53590287; called by muse, mutect2, varscan2
- GRID2IP | c.409G>T p.A137S | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as rs1253425278; called by muse, mutect2, varscan2
- GRIN2A | c.3041G>T p.W1014L | Missense Mutation (SNP) | VAF 171/271 reads (63%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV58021616; called by muse, mutect2, varscan2
- GRM1 | c.1073G>T p.R358M | Missense Mutation (SNP) | VAF 88/455 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as rs112817798, COSV51110029; called by muse, mutect2, varscan2
- GRM1 | c.2047G>T p.A683S | Missense Mutation (SNP) | VAF 32/122 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV51110049; called by muse, mutect2, varscan2
- GRM5 | c.577C>T p.P193S | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100552079, COSV59592411, COSV59625583; called by muse, mutect2, varscan2
- GSDMB | c.346C>T p.Q116* | Nonsense Mutation (SNP) | VAF 38/156 reads (24%) | catalogued as COSV58779713; called by muse, mutect2, varscan2
- GTF3C2 | c.2418C>G p.F806L | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.696); catalogued as COSV51989493; called by muse, mutect2, varscan2
- GTF3C3 | c.962A>T p.Q321L | Missense Mutation (SNP) | VAF 31/137 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.169); catalogued as COSV55831075; called by muse, mutect2, varscan2
- H2AC1 | c.128G>T p.R43L | Missense Mutation (SNP) | VAF 104/248 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.205); catalogued as COSV51236783, COSV51238650; called by muse, mutect2, varscan2
- H2AC11 | c.19C>T p.Q7* | Nonsense Mutation (SNP) | VAF 26/81 reads (32%) | catalogued as rs369680334; called by muse, mutect2, varscan2
- H2BC7 | c.88C>G p.R30G | Missense Mutation (SNP) | VAF 43/208 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV61911585; called by muse, mutect2, varscan2
- HAS1 | c.919G>T p.G307C | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55786297, COSV55787865; called by muse, mutect2
- HAVCR1 | c.697C>T p.Q233* | Nonsense Mutation (SNP) | VAF 26/199 reads (13%) | catalogued as rs530402371, COSV59397969; called by muse, mutect2, varscan2
- HCN1 | c.2140G>T p.A714S | Missense Mutation (SNP) | VAF 37/126 reads (29%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0); catalogued as rs775543627, COSV57495256; called by muse, mutect2, varscan2
- HDAC11 | c.190C>T p.R64W | Missense Mutation (SNP) | VAF 46/111 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.892); catalogued as rs773395422, COSV55472472; called by muse, mutect2, varscan2
- HDAC4 | c.169T>A p.F57I | Missense Mutation (SNP) | VAF 31/146 reads (21%) | SIFT tolerated (0.44); PolyPhen benign (0.055); catalogued as COSV61860061; called by muse, mutect2, varscan2
- HDAC9 | c.199G>C p.E67Q | Missense Mutation (SNP) | VAF 57/292 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV67772473; called by muse, mutect2, varscan2
- HEATR5B | c.5236C>T p.R1746* | Nonsense Mutation (SNP) | VAF 86/403 reads (21%) | catalogued as rs764726800, COSV51849345; called by muse, mutect2, varscan2
- HELT | c.92A>G p.N31S | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT tolerated (0.99); PolyPhen benign (0.005); catalogued as COSV58819657; called by muse, mutect2, varscan2
- HELT | c.460C>A p.P154T | Missense Mutation (SNP) | VAF 45/91 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV58819668; called by muse, mutect2, varscan2
- HEPACAM | c.187G>C p.D63H | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53428829; called by muse, mutect2
- HERC2 | c.13202G>C p.R4401P | Missense Mutation (SNP) | VAF 47/77 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55309383; called by muse, mutect2, varscan2
- HES4 | c.484G>T p.A162S | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.53); PolyPhen benign (0.037); catalogued as COSV59241902; called by muse, mutect2, varscan2
- HEXIM1 | c.146C>G p.S49W | Missense Mutation (SNP) | VAF 60/337 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.753); catalogued as COSV60176710; called by muse, mutect2, varscan2
- HGF | c.1457C>G p.S486C | Missense Mutation (SNP) | VAF 145/203 reads (71%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.628); catalogued as COSV55945339, COSV55945824; called by muse, mutect2, varscan2
- HHIPL2 | c.1161G>C p.R387S | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV58563347; called by muse, mutect2
- HIVEP1 | c.1858G>A p.E620K | Missense Mutation (SNP) | VAF 26/191 reads (14%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.516); catalogued as COSV65098965; called by muse, mutect2, varscan2
- HLTF | c.563C>A p.S188Y | Missense Mutation (SNP) | VAF 75/134 reads (56%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.987); catalogued as COSV59498945; called by muse, mutect2, varscan2
- HMCN1 | c.3130G>A p.E1044K | Missense Mutation (SNP) | VAF 76/312 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.329); catalogued as COSV54879699; called by muse, mutect2, varscan2
- HMCN1 | c.16855G>A p.E5619K | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.215); catalogued as COSV54879715; called by muse, mutect2, varscan2
- HMX2 | c.734C>G p.S245W | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV60592433; called by muse, mutect2, varscan2
- HMX3 | c.13G>T p.G5W | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.892); catalogued as COSV63501489; called by muse, mutect2, varscan2
- HOOK2 | c.1761G>C p.Q587H | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV53401416; called by muse, mutect2, varscan2
- HOXA4 | c.48G>T p.K16N | Missense Mutation (SNP) | VAF 171/506 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as COSV57825220; called by muse, varscan2
- HOXB9 | c.403G>T p.E135* | Nonsense Mutation (SNP) | VAF 40/108 reads (37%) | catalogued as COSV60816715, COSV60817693; called by muse, mutect2, varscan2
- HOXD10 | c.646G>C p.V216L | Missense Mutation (SNP) | VAF 141/565 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs939576278, COSV50890721; called by muse, mutect2, varscan2
- HSD11B1 | c.335G>C p.G112A | Missense Mutation (SNP) | VAF 101/353 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.654); catalogued as COSV54826057; called by muse, mutect2, varscan2
- HSD11B1 | c.683C>T p.S228F | Missense Mutation (SNP) | VAF 49/212 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); catalogued as COSV54826070; called by muse, mutect2, varscan2
- HSP90AB1 | c.1525G>C p.E509Q | Missense Mutation (SNP) | VAF 86/302 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62333273, COSV62334402; called by muse, mutect2, varscan2
- HSPA12A | c.1915C>G p.R639G | Missense Mutation (SNP) | VAF 69/277 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as COSV65020914; called by muse, mutect2, varscan2
- HTR1A | c.759T>A p.S253R | Missense Mutation (SNP) | VAF 111/180 reads (62%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as COSV60499963; called by muse, mutect2, varscan2
- HTR1E | c.799C>A p.P267T | Missense Mutation (SNP) | VAF 36/179 reads (20%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as rs142001331, COSV59506830, COSV59509254; called by muse, mutect2, varscan2
- HTT | c.206C>T p.P69L | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.354); catalogued as rs1461748315; called by muse, varscan2
- HUWE1 | c.12416A>G p.K4139R | Missense Mutation (SNP) | VAF 79/426 reads (19%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.956); catalogued as COSV53335756; called by muse, mutect2, varscan2
- IBTK | c.2581G>C p.E861Q | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.883); catalogued as COSV60391028; called by muse, mutect2, varscan2
- ICE1 | c.2977G>T p.D993Y | Missense Mutation (SNP) | VAF 86/235 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.413); catalogued as COSV56819613; called by muse, mutect2, varscan2
- ICE1 | c.3679G>T p.E1227* | Nonsense Mutation (SNP) | VAF 47/286 reads (16%) | catalogued as COSV56819634; called by muse, mutect2, varscan2
- IFIH1 | c.2422G>T p.G808C | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.278); catalogued as COSV55124803; called by muse, mutect2, varscan2
- IGFBP6 | c.461G>A p.G154D | Missense Mutation (SNP) | VAF 34/131 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.709); catalogued as COSV56857080; called by muse, mutect2, varscan2
- IGHMBP2 | c.2828G>A p.R943K | Missense Mutation (SNP) | VAF 38/140 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.411); catalogued as rs779871930, COSV54819863, COSV54820280, COSV54825435; called by muse, mutect2, varscan2
- IGHV2-5 | c.235C>T p.R79C | Missense Mutation (SNP) | VAF 59/292 reads (20%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.495); catalogued as rs782632670; called by muse, mutect2, varscan2
- IGLV3-27 | c.215G>T p.R72L | Missense Mutation (SNP) | VAF 63/258 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.097); catalogued as rs370712523; called by muse, mutect2, varscan2
- IGSF10 | c.3074C>G p.P1025R | Missense Mutation (SNP) | VAF 32/189 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.133); catalogued as COSV56782044; called by muse, mutect2, varscan2
- IKZF2 | c.365T>A p.I122N | Missense Mutation (SNP) | VAF 126/237 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV59576748; called by muse, mutect2, varscan2
- IL16 | c.596C>A p.T199K | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV57260667; called by muse, mutect2, varscan2
- IL1R1 | c.1084G>T p.D362Y | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52104766; called by muse, mutect2, varscan2
- IL1R2 | c.46C>A p.L16I | Missense Mutation (SNP) | VAF 34/163 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60205804, COSV60210082; called by muse, mutect2, varscan2
- IL26 | c.43A>T p.T15S | Missense Mutation (SNP) | VAF 50/119 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.142); catalogued as COSV57488336; called by muse, mutect2, varscan2
- IL6R | c.849G>C p.W283C | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.874); catalogued as COSV59815498; called by muse, mutect2, varscan2
- IMPG1 | c.1269C>A p.D423E | Missense Mutation (SNP) | VAF 20/170 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.074); catalogued as rs758038128, COSV64054519, COSV64057625; called by muse, mutect2, varscan2
- INHBA | c.917G>A p.R306H | Missense Mutation (SNP) | VAF 56/141 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as rs1202073030, COSV54219397, COSV54221649; called by muse, mutect2, varscan2
- INHBC | c.696G>T p.Q232H | Missense Mutation (SNP) | VAF 51/98 reads (52%) | SIFT tolerated (0.17); PolyPhen benign (0.033); catalogued as COSV59004624; called by muse, mutect2, varscan2
- INSC | c.1429C>A p.P477T | Missense Mutation (SNP) | VAF 35/75 reads (47%) | SIFT tolerated (0.27); PolyPhen benign (0.083); catalogued as rs764430228, COSV65408946; called by muse, mutect2, varscan2
- INSRR | c.809A>T p.E270V | Missense Mutation (SNP) | VAF 30/54 reads (56%) | SIFT deleterious (0.03); PolyPhen benign (0.426); catalogued as COSV63871123; called by muse, mutect2, varscan2
- INSYN2A | c.283T>A p.S95T | Missense Mutation (SNP) | VAF 63/154 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.942); catalogued as COSV54731030; called by muse, mutect2, varscan2
- IPO7 | c.1054G>A p.D352N | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.756); catalogued as COSV63352559; called by muse, mutect2, varscan2
- IRF2BP2 | c.625G>A p.A209T | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.104); catalogued as COSV64014613; called by muse, mutect2, varscan2
- ITGA8 | c.215G>T p.S72I | Missense Mutation (SNP) | VAF 84/193 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as rs1393135685, COSV65225054; called by muse, mutect2, varscan2
- ITGB5 | c.2278G>T p.E760* | Nonsense Mutation (SNP) | VAF 64/148 reads (43%) | catalogued as COSV56146745; called by muse, mutect2, varscan2
- ITGBL1 | c.424A>T p.M142L | Missense Mutation (SNP) | VAF 64/88 reads (73%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as COSV66005564; called by muse, mutect2, varscan2
- ITGBL1 | c.796G>A p.G266R | Missense Mutation (SNP) | VAF 39/116 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775230281, COSV66005576; called by muse, mutect2, varscan2
- ITIH2 | c.1730C>A p.P577H | Missense Mutation (SNP) | VAF 58/244 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.969); catalogued as COSV64432058; called by muse, mutect2, varscan2
- ITIH6 | c.2822G>T p.W941L | Missense Mutation (SNP) | VAF 56/63 reads (89%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as COSV54486855; called by muse, mutect2, varscan2
- ITPR1 | c.742G>C p.E248Q | Missense Mutation (SNP) | VAF 44/214 reads (21%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.993); catalogued as COSV56969479; called by muse, varscan2
- ITPR1 | c.4917G>C p.E1639D (on ENST00000354582; = p.E1624D on NM_002222.7) | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.995); catalogued as COSV56970482; called by muse, mutect2, varscan2
- ITPRID1 | c.1423C>A p.P475T | Missense Mutation (SNP) | VAF 47/302 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.023); catalogued as COSV60070579, COSV60072018; called by muse, mutect2, varscan2
- KANK3 | c.1024G>C p.E342Q | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV58359034; called by muse, mutect2, varscan2
- KAT2B | c.1112C>G p.S371* | Nonsense Mutation (SNP) | VAF 13/75 reads (17%) | catalogued as COSV55426997; called by muse, mutect2, varscan2
- KCNF1 | c.900C>G p.I300M | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV54462135; called by muse, mutect2, varscan2
- KCNMB4 | c.115T>C p.W39R | Missense Mutation (SNP) | VAF 64/151 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); catalogued as COSV50690747; called by muse, mutect2, varscan2
- KCNT2 | c.3402A>T p.Q1134H | Missense Mutation (SNP) | VAF 35/135 reads (26%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as COSV54065467; called by muse, mutect2, varscan2
- KCNV2 | c.362C>A p.T121K | Missense Mutation (SNP) | VAF 69/153 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66055580; called by muse, mutect2, varscan2
- KDM2A | c.1346G>T p.R449M | Missense Mutation (SNP) | VAF 75/257 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.087); catalogued as COSV67081209; called by muse, mutect2, varscan2
- KDM3B | c.1198G>C p.G400R | Missense Mutation (SNP) | VAF 128/196 reads (65%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.844); catalogued as COSV58688251; called by muse, mutect2, varscan2
- KDM5C | c.4099G>A p.E1367K | Missense Mutation (SNP) | VAF 89/438 reads (20%) | SIFT tolerated (0.81); PolyPhen benign (0.001); catalogued as COSV64762976; called by muse, mutect2, varscan2
- KDM5C | c.1056C>G p.F352L | Missense Mutation (SNP) | VAF 70/282 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV64765760; called by muse, mutect2, varscan2
- KIAA0100 | c.6075G>C p.M2025I | Missense Mutation (SNP) | VAF 17/183 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV56380841; called by muse, mutect2
- KIAA0100 | c.244C>T p.L82F | Missense Mutation (SNP) | VAF 25/146 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as rs529279757, COSV55931480; called by muse, mutect2, varscan2
- KIAA1549L | c.3077C>A p.A1026D (on ENST00000321505; = p.A1323D on NM_012194.3) | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55770029, COSV55775624; called by muse, mutect2, varscan2
- KIDINS220 | c.3353C>T p.P1118L | Missense Mutation (SNP) | VAF 41/167 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as COSV56750751; called by muse, mutect2, varscan2
- KIF2B | c.1646C>A p.P549H | Missense Mutation (SNP) | VAF 31/174 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV52127349; called by muse, mutect2, varscan2
- KISS1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 110/419 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.303); catalogued as COSV65816888; called by muse, mutect2, varscan2
- KLF1 | c.124G>T p.G42C | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.907); catalogued as COSV53434549; called by muse, mutect2, varscan2
- KLF14 | c.602G>T p.G201V | Missense Mutation (SNP) | VAF 190/295 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100205830, COSV60588421; called by muse, mutect2, varscan2
- KLHL13 | c.483G>C p.M161I | Missense Mutation (SNP) | VAF 30/115 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.105); catalogued as COSV53244984, COSV53249868, COSV99035215; called by muse, mutect2, varscan2
- KMT2B | c.3236G>C p.C1079S | Missense Mutation (SNP) | VAF 47/455 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as COSV55857579; called by muse, mutect2, varscan2
- KMT2B | c.7261G>A p.E2421K | Missense Mutation (SNP) | VAF 48/580 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.371); catalogued as COSV55819957; called by muse, mutect2
- KMT2E | c.5545C>G p.Q1849E | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.857); catalogued as COSV57569891; called by muse, mutect2, varscan2
- KPTN | c.343A>G p.I115V | Missense Mutation (SNP) | VAF 45/144 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.302); catalogued as COSV54548798; called by muse, mutect2, varscan2
- KRT12 | c.541C>G p.P181A | Missense Mutation (SNP) | VAF 42/218 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV52429855; called by muse, mutect2, varscan2
- KRT24 | c.116C>A p.S39* | Nonsense Mutation (SNP) | VAF 20/87 reads (23%) | catalogued as COSV52879612; called by muse, mutect2, varscan2
- KRT26 | c.239C>G p.S80C | Missense Mutation (SNP) | VAF 62/302 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.063); catalogued as COSV56970872; called by muse, mutect2, varscan2
- KRT74 | c.517G>T p.E173* | Nonsense Mutation (SNP) | VAF 106/439 reads (24%) | catalogued as COSV59770614; called by muse, mutect2, varscan2
- KRT75 | c.1430C>G p.S477C | Missense Mutation (SNP) | VAF 64/296 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.52); catalogued as rs1292114043, COSV52871168; called by muse, mutect2, varscan2
- KRT75 | c.736C>A p.R246S | Missense Mutation (SNP) | VAF 112/252 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs779742513, COSV52871179, COSV52873294; called by muse, mutect2, varscan2
- KRTAP10-8 | c.303G>C p.Q101H | Missense Mutation (SNP) | VAF 124/565 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as rs1555931308, COSV58165982; called by muse, mutect2, varscan2
- KRTAP11-1 | c.308C>A p.P103Q | Missense Mutation (SNP) | VAF 93/309 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV60094064; called by muse, mutect2, varscan2
- KRTAP23-1 | c.77G>C p.R26P | Missense Mutation (SNP) | VAF 62/262 reads (24%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.166); catalogued as COSV61935525, COSV61935651; called by muse, mutect2, varscan2
- LALBA | c.428G>T p.*143Lext*42 | Nonstop Mutation (SNP) | VAF 29/172 reads (17%) | catalogued as COSV99974376; called by muse, mutect2, varscan2
- LAMA1 | c.8695G>T p.G2899* | Nonsense Mutation (SNP) | VAF 150/328 reads (46%) | catalogued as COSV67532592; called by muse, mutect2, varscan2
- LAMA1 | c.7338G>C p.R2446S | Missense Mutation (SNP) | VAF 136/309 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.577); catalogued as COSV67532594; called by muse, mutect2, varscan2
- LAMA1 | c.3037G>C p.E1013Q | Missense Mutation (SNP) | VAF 42/300 reads (14%) | SIFT tolerated (0.97); PolyPhen benign (0.187); catalogued as rs779107120; called by muse, mutect2, varscan2
- LAMA2 | c.4443C>G p.S1481R | Missense Mutation (SNP) | VAF 99/257 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV70339517; called by muse, mutect2, varscan2
- LAMA2 | c.6704C>G p.S2235* | Nonsense Mutation (SNP) | VAF 27/156 reads (17%) | catalogued as rs1193735558, COSV70339521; called by muse, mutect2
- LAMA3 | c.1145G>C p.G382A | Missense Mutation (SNP) | VAF 197/414 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV58063106; called by muse, mutect2, varscan2
- LAMA4 | c.284C>A p.S95* | Nonsense Mutation (SNP) | VAF 64/304 reads (21%) | catalogued as COSV54568739; called by muse, mutect2, varscan2
- LCE1A | c.37C>T p.P13S | Missense Mutation (SNP) | VAF 93/160 reads (58%) | SIFT tolerated, low confidence (0.5); PolyPhen probably damaging (0.996); catalogued as COSV58726476; called by muse, mutect2, varscan2
- LCORL | c.1582G>A p.E528K | Missense Mutation (SNP) | VAF 45/204 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.287); catalogued as COSV58833006, COSV58835305; called by muse, mutect2, varscan2
- LENG9 | c.544C>T p.Q182* | Nonsense Mutation (SNP) | VAF 62/191 reads (32%) | catalogued as COSV56617547; called by muse, mutect2, varscan2
- LGI4 | c.812G>T p.C271F | Missense Mutation (SNP) | VAF 40/480 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59532717; called by muse, mutect2
- LGR4 | c.1849G>T p.G617C | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64863534; called by muse, mutect2, varscan2
- LHX8 | c.40G>T p.E14* | Nonsense Mutation (SNP) | VAF 53/198 reads (27%) | catalogued as COSV53954574; called by muse, mutect2, varscan2
- LIG1 | c.420G>C p.Q140H | Missense Mutation (SNP) | VAF 98/289 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs1231791578, COSV54389729; called by muse, mutect2, varscan2
- LILRA4 | c.974C>A p.S325Y | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV52490450; called by muse, mutect2
- LILRB4 | c.124G>A p.G42R | Missense Mutation (SNP) | VAF 59/172 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.052); catalogued as COSV54403617; called by muse, mutect2, varscan2
- LILRB4 | c.125G>T p.G42V | Missense Mutation (SNP) | VAF 59/173 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as COSV54403634; called by muse, mutect2, varscan2
- LIMCH1 | c.2716C>T p.H906Y | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT tolerated (0.27); PolyPhen benign (0.175); catalogued as rs1344323864, COSV58274449; called by muse, mutect2, varscan2
- LIN7A | c.542G>T p.S181I | Missense Mutation (SNP) | VAF 32/185 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.689); catalogued as COSV54018296; called by muse, mutect2, varscan2
- LMBRD1 | c.1212G>T p.M404I (on ENST00000649011; = p.M382I on NM_018368.4) | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as COSV65296228; called by muse, mutect2
- LPA | c.5424G>C p.K1808N | Missense Mutation (SNP) | VAF 32/226 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV60297519; called by muse, mutect2, varscan2
- LRIT1 | c.1654C>A p.L552I | Missense Mutation (SNP) | VAF 61/238 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.056); catalogued as COSV64512003; called by muse, mutect2, varscan2
- LRP1B | c.12997G>A p.E4333K | Missense Mutation (SNP) | VAF 50/160 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV67189793; called by muse, mutect2, varscan2
- LRP1B | c.11330T>A p.M3777K | Missense Mutation (SNP) | VAF 60/237 reads (25%) | SIFT tolerated (0.92); PolyPhen benign (0.001); catalogued as COSV67189802; called by muse, mutect2, varscan2
- LRP1B | c.11140C>T p.L3714F | Missense Mutation (SNP) | VAF 43/173 reads (25%) | SIFT tolerated (0.7); PolyPhen benign (0.047); catalogued as rs1336711239, COSV67185170, COSV67189807; called by muse, mutect2, varscan2
- LRP1B | c.10471G>T p.D3491Y | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.98); catalogued as COSV67185308, COSV67189813; called by muse, mutect2, varscan2
- LRP1B | c.1085C>A p.T362K | Missense Mutation (SNP) | VAF 57/126 reads (45%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); catalogued as COSV67189816, COSV67273214; called by muse, mutect2, varscan2
- LRP1B | c.772C>T p.Q258* | Nonsense Mutation (SNP) | VAF 21/126 reads (17%) | catalogued as COSV67181908, COSV67189822, COSV67243070; called by muse, mutect2, varscan2
- LRP2 | c.2162G>T p.G721V | Missense Mutation (SNP) | VAF 116/217 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55542066; called by muse, mutect2, varscan2
- LRRC69 | c.87G>T p.M29I | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV59248613, COSV59249426; called by muse, mutect2, varscan2
- LRRC7 | c.2098G>A p.D700N (on ENST00000651989 / NM_001370785.2; = p.D667N on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.891); catalogued as COSV50414521; called by muse, mutect2, varscan2
- LRRC7 | c.2252C>G p.A751G (on ENST00000651989 / NM_001370785.2; = p.A718G on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 44/109 reads (40%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.011); catalogued as COSV50414558, COSV50485589; called by muse, mutect2, varscan2
- LRRC7 | c.4511G>A p.S1504N (on ENST00000651989 / NM_001370785.2; = p.S1424N on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV50414584; called by muse, mutect2, varscan2
- LRRK1 | c.4255G>T p.E1419* | Nonsense Mutation (SNP) | VAF 11/54 reads (20%) | catalogued as COSV52602922, COSV52625083; called by muse, varscan2
- LSAMP | c.107G>A p.R36Q | Missense Mutation (SNP) | VAF 137/426 reads (32%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.65); catalogued as COSV61276942; called by muse, mutect2, varscan2
- LYST | c.9280G>T p.G3094C | Missense Mutation (SNP) | VAF 49/219 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67702816, COSV67703642; called by muse, mutect2, varscan2
- MACO1 | c.784G>C p.D262H | Missense Mutation (SNP) | VAF 72/149 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV65475131, COSV65476102; called by muse, mutect2, varscan2
- MAG | c.748G>C p.E250Q | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.405); catalogued as COSV62699099, COSV62702817; called by muse, mutect2
- MAGEB1 | c.771C>A p.Y257* | Nonsense Mutation (SNP) | VAF 131/302 reads (43%) | catalogued as rs766373792, COSV66775251, COSV66775580; called by muse, mutect2, varscan2
- MAGEB3 | c.494G>T p.G165V | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV64396779; called by muse, mutect2
- MAGEB6 | c.256G>C p.A86P | Missense Mutation (SNP) | VAF 287/325 reads (88%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.486); catalogued as COSV66871931, COSV66872393; called by muse, mutect2, varscan2
- MAGEB6 | c.866T>A p.M289K | Missense Mutation (SNP) | VAF 39/161 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV66871936; called by muse, mutect2, varscan2
- MAGEE2 | c.259C>A p.P87T | Missense Mutation (SNP) | VAF 107/142 reads (75%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); catalogued as COSV64897338; called by muse, mutect2, varscan2
- MAP2K4 | c.205C>G p.Q69E | Missense Mutation (SNP) | VAF 33/115 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs1394118458, COSV62255195, COSV62256646; called by muse, mutect2, varscan2
- MAP2K5 | c.446C>A p.S149Y | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as COSV51610714; called by muse, mutect2, varscan2
- MAP3K1 | c.2463G>C p.L821F | Missense Mutation (SNP) | VAF 47/164 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV68121895; called by muse, mutect2, varscan2
- MAP3K13 | c.2578G>A p.E860K | Missense Mutation (SNP) | VAF 58/390 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as COSV53984006, COSV53988707; called by muse, mutect2, varscan2
- MAP3K19 | c.2449G>C p.E817Q | Missense Mutation (SNP) | VAF 33/142 reads (23%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as COSV59636817, COSV59638037; called by muse, mutect2, varscan2
- MAP3K21 | c.673G>A p.G225S | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.037); catalogued as rs1357192577, COSV64043486; called by muse, mutect2, varscan2
- MAP3K4 | c.3675G>T p.R1225S | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.678); catalogued as COSV62330303; called by muse, mutect2, varscan2
- MAP4K2 | c.1301G>A p.G434D | Missense Mutation (SNP) | VAF 53/151 reads (35%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs530729964, COSV53640605; called by muse, mutect2, varscan2
- MARCHF7 | c.785C>T p.S262L | Missense Mutation (SNP) | VAF 36/159 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.477); catalogued as COSV104386625, COSV52027634; called by muse, mutect2, varscan2
- MARK4 | c.333G>T p.K111N | Missense Mutation (SNP) | VAF 25/255 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53461772; called by muse, mutect2, varscan2
- MAST1 | c.4604C>G p.S1535* | Nonsense Mutation (SNP) | VAF 11/36 reads (31%) | catalogued as COSV52241540; called by muse, mutect2, varscan2
- MAST2 | c.2587G>A p.E863K | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.522); catalogued as rs559530509, COSV63616284; called by muse, mutect2, varscan2
- MATN4 | c.736A>T p.K246* | Nonsense Mutation (SNP) | VAF 29/138 reads (21%) | catalogued as rs1327916368; called by muse, mutect2, varscan2
- MBOAT1 | c.1244C>G p.S415* | Nonsense Mutation (SNP) | VAF 26/129 reads (20%) | catalogued as COSV100208808, COSV61123667; called by muse, mutect2, varscan2
- MBOAT1 | c.728A>T p.H243L | Missense Mutation (SNP) | VAF 44/112 reads (39%) | SIFT tolerated (0.3); PolyPhen benign (0.082); catalogued as COSV61123672; called by muse, mutect2, varscan2
- MCHR2 | c.514T>A p.S172T | Missense Mutation (SNP) | VAF 57/132 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.224); catalogued as COSV55999978; called by muse, mutect2, varscan2
- MCU | c.833T>A p.M278K | Missense Mutation (SNP) | VAF 169/327 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.158); catalogued as COSV64064783; called by muse, mutect2, varscan2
- MDN1 | c.848G>T p.G283V | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV65517633; called by muse, mutect2, varscan2
- MED12L | c.3955G>A p.E1319K | Missense Mutation (SNP) | VAF 43/214 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.034); catalogued as COSV56369595; called by muse, mutect2, varscan2
- MED12L | c.5409G>A p.M1803I | Missense Mutation (SNP) | VAF 52/359 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.708); catalogued as COSV56369606; called by muse, mutect2, varscan2
- MED25 | c.679G>C p.V227L | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.855); catalogued as COSV57203115; called by muse, mutect2
- MEGF10 | c.512C>T p.A171V | Missense Mutation (SNP) | VAF 37/59 reads (63%) | SIFT deleterious (0.02); PolyPhen benign (0.39); catalogued as rs201824269, COSV57245319; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- METRN | c.454G>T p.E152* | Nonsense Mutation (SNP) | VAF 20/60 reads (33%) | catalogued as COSV54801173; called by muse, mutect2, varscan2
- MGAT2 | c.900C>G p.F300L | Missense Mutation (SNP) | VAF 59/187 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.542); catalogued as COSV53565614; called by muse, mutect2, varscan2
- MICAL1 | c.2296G>C p.E766Q | Missense Mutation (SNP) | VAF 34/197 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.034); catalogued as COSV57804347; called by muse, mutect2, varscan2
- MIGA1 | c.17C>T p.S6L | Missense Mutation (SNP) | VAF 47/132 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.062); catalogued as COSV66222853; called by muse, mutect2, varscan2
- MKI67 | c.9346G>C p.E3116Q | Missense Mutation (SNP) | VAF 53/148 reads (36%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV64072749; called by muse, mutect2, varscan2
- MKI67 | c.2474C>G p.S825C | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.85); catalogued as COSV64072755; called by muse, mutect2, varscan2
- MLF1 | c.248G>C p.R83T | Missense Mutation (SNP) | VAF 34/229 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as COSV63032698; called by muse, mutect2, varscan2
- MLH1 | c.1972C>T p.L658F | Missense Mutation (SNP) | VAF 63/140 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.709); catalogued as COSV51614759, COSV51623040; called by muse, mutect2, varscan2
- MLIP | c.612G>T p.Q204H | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1434931785, COSV51426282, COSV51430186; called by muse, mutect2, varscan2
- MLST8 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 10/28 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.38); catalogued as COSV57026650; called by muse, varscan2
- MMP16 | c.1571C>G p.S524C | Missense Mutation (SNP) | VAF 107/149 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV54152377; called by muse, mutect2, varscan2
- MMRN1 | c.1009C>T p.L337F | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.44); PolyPhen benign (0.422); catalogued as COSV53333985, COSV99306872; called by muse, mutect2, varscan2
- MOCOS | c.939G>A p.Q313= | Splice Region (SNP) | VAF 15/68 reads (22%) | catalogued as COSV54341252; called by muse, mutect2, varscan2
- MON2 | c.5115G>A p.M1705I | Missense Mutation (SNP) | VAF 47/178 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.018); catalogued as COSV54803597; called by muse, mutect2, varscan2
- MRPL34 | c.105G>C p.W35C | Missense Mutation (SNP) | VAF 17/70 reads (24%) | catalogued as COSV99917227; called by muse, mutect2, varscan2
- MS4A5 | c.350G>T p.S117I | Missense Mutation (SNP) | VAF 448/492 reads (91%) | SIFT deleterious (0.02); PolyPhen benign (0.353); catalogued as COSV55739976; called by muse, mutect2, varscan2
- MS4A8 | c.94C>T p.H32Y | Missense Mutation (SNP) | VAF 72/2116 reads (3%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV55753222, COSV55753402; called by muse, mutect2
- MSH2 | c.2567A>G p.Y856C | Missense Mutation (SNP) | VAF 67/250 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.019); catalogued as rs587779150, COSV51875935; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MTERF4 | c.931G>C p.E311Q | Missense Mutation (SNP) | VAF 84/360 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.634); catalogued as COSV54087957; called by muse, mutect2, varscan2
- MTERF4 | c.341G>T p.S114I | Missense Mutation (SNP) | VAF 34/152 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV54087975; called by muse, mutect2, varscan2
- MTMR11 | c.198G>T p.L66F | Missense Mutation (SNP) | VAF 24/157 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as COSV63804935; called by muse, mutect2, varscan2
- MTMR14 | c.1351G>A p.E451K | Missense Mutation (SNP) | VAF 76/343 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0.023); catalogued as COSV56003380; called by muse, mutect2, varscan2
- MTMR3 | c.2285C>G p.S762* | Nonsense Mutation (SNP) | VAF 79/282 reads (28%) | catalogued as COSV60302019, COSV60306149; called by muse, mutect2, varscan2
- MUC12 | c.554C>G p.S185* (on ENST00000379442; = p.S42* on NM_001164462.1) | Nonsense Mutation (SNP) | VAF 63/287 reads (22%) | catalogued as rs1402613858, COSV65185753; called by muse, mutect2, varscan2
- MUC12 | c.15037A>T p.T5013S (on ENST00000379442; = p.T4870S on NM_001164462.1) | Missense Mutation (SNP) | VAF 137/281 reads (49%) | SIFT deleterious (0.01); catalogued as COSV65185764; called by muse, mutect2, varscan2
- MUC12 | c.15938C>A p.T5313N (on ENST00000379442; = p.T5170N on NM_001164462.1) | Missense Mutation (SNP) | VAF 127/167 reads (76%) | SIFT deleterious (0.01); catalogued as COSV59331046; called by muse, mutect2, varscan2
- MUC4 | c.8807C>G p.S2936* | Nonsense Mutation (SNP) | VAF 90/741 reads (12%) | catalogued as COSV57793560; called by muse, mutect2, varscan2
- MYF6 | c.274A>G p.T92A | Missense Mutation (SNP) | VAF 96/417 reads (23%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.946); catalogued as COSV57350824; called by muse, mutect2, varscan2
- MYH4 | c.3021C>A p.H1007Q | Missense Mutation (SNP) | VAF 208/325 reads (64%) | SIFT tolerated (0.08); PolyPhen benign (0.299); catalogued as COSV55112844; called by muse, mutect2, varscan2
- MYO15A | c.185G>T p.G62V | Missense Mutation (SNP) | VAF 181/275 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV52752366; called by muse, mutect2, varscan2
- MYO3A | c.1779A>G p.Q593= | Splice Region (SNP) | VAF 123/325 reads (38%) | catalogued as rs977427777, COSV56320837; called by muse, mutect2, varscan2
- MYO3B | c.632C>G p.S211C | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.95); catalogued as COSV58695346; called by muse, mutect2, varscan2
- MYO3B | c.1710C>A p.H570Q | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV58695369; called by mutect2, varscan2
- MYO6 | c.2630C>G p.S877C | Missense Mutation (SNP) | VAF 54/297 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.545); catalogued as COSV64117581; called by muse, mutect2, varscan2
- MYRIP | c.1391G>A p.R464Q | Missense Mutation (SNP) | VAF 39/76 reads (51%) | SIFT tolerated (0.13); PolyPhen benign (0.04); catalogued as rs149356378; called by muse, mutect2, varscan2
- MYSM1 | c.1828G>C p.D610H | Missense Mutation (SNP) | VAF 44/145 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.754); catalogued as rs1348085300, COSV68976996; called by muse, mutect2, varscan2
- MZF1 | c.850G>T p.G284C | Missense Mutation (SNP) | VAF 28/49 reads (57%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.496); catalogued as COSV53040744; called by muse, mutect2, varscan2
- N4BP2L2 | c.2493G>C p.K831N (on ENST00000674422; = p.K402N on NM_033111.4) | Missense Mutation (SNP) | VAF 48/120 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62631593; called by muse, mutect2, varscan2
- NAALADL2 | c.1969G>A p.E657K | Missense Mutation (SNP) | VAF 30/226 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.419); catalogued as COSV71983659; called by muse, mutect2, varscan2
- NAGA | c.665G>T p.W222L | Missense Mutation (SNP) | VAF 146/242 reads (60%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.934); catalogued as COSV67169732; called by muse, mutect2, varscan2
- NAIP | c.64G>C p.E22Q | Missense Mutation (SNP) | VAF 48/128 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.024); catalogued as COSV52000511; called by muse, mutect2, varscan2
- NALCN | c.294G>T p.G98= | Splice Region (SNP) | VAF 22/104 reads (21%) | catalogued as COSV51919581, COSV51965395; called by muse, mutect2, varscan2
- NAMPT | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.052); catalogued as COSV55994220; called by muse, mutect2, varscan2
- NAV3 | c.5312G>A p.W1771* | Nonsense Mutation (SNP) | VAF 32/129 reads (25%) | catalogued as rs1358763306; called by muse, mutect2, varscan2
- NAV3 | c.7120G>A p.E2374K (on ENST00000397909 / NM_001024383.2; = p.E2352K on NM_014903.6) | Missense Mutation (SNP) | VAF 30/140 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.054); catalogued as COSV57063754; called by muse, mutect2, varscan2
- NBAS | c.4694C>T p.S1565F | Missense Mutation (SNP) | VAF 40/234 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.11); catalogued as COSV55723305; called by muse, mutect2, varscan2
- NBEAL2 | c.4627G>A p.E1543K | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated (0.88); PolyPhen benign (0.09); catalogued as COSV52754572; called by muse, mutect2
- NBN | c.262T>A p.S88T | Missense Mutation (SNP) | VAF 123/166 reads (74%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.683); catalogued as COSV55371398; called by muse, mutect2, varscan2
- NCALD | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.059); catalogued as COSV55271201, COSV55275038; called by muse, mutect2, varscan2
- NCAPD2 | c.532C>T p.Q178* | Nonsense Mutation (SNP) | VAF 29/96 reads (30%) | catalogued as rs777889802, COSV59697973; called by muse, mutect2, varscan2
- NCAPG2 | c.1303G>T p.D435Y | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV51984997; called by muse, mutect2, varscan2
- NCCRP1 | c.176C>A p.P59H | Missense Mutation (SNP) | VAF 263/319 reads (82%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.75); catalogued as rs749672819, COSV60430960; called by muse, mutect2, varscan2
- NCKAP5 | c.4951C>G p.Q1651E | Missense Mutation (SNP) | VAF 29/172 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); catalogued as COSV58429106; called by muse, mutect2, varscan2
- NCKAP5 | c.275A>T p.Q92L | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.02); catalogued as COSV58429119; called by muse, mutect2, varscan2
- NCOA3 | c.2290A>T p.N764Y | Missense Mutation (SNP) | VAF 74/170 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.163); catalogued as COSV59065983; called by muse, mutect2, varscan2
- NEB | c.14227G>C p.E4743Q | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as COSV50819127; called by muse, mutect2, varscan2
- NEB | c.8730G>T p.W2910C | Missense Mutation (SNP) | VAF 39/194 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50819273; called by muse, mutect2, varscan2
- NEB | c.8729G>T p.W2910L | Missense Mutation (SNP) | VAF 38/191 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV50819410; called by muse, mutect2, varscan2
- NEB | c.8323G>A p.D2775N | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50819571; called by muse, mutect2, varscan2
- NEMF | c.2851C>A p.H951N | Missense Mutation (SNP) | VAF 134/274 reads (49%) | SIFT tolerated (0.46); PolyPhen benign (0.006); catalogued as COSV53589190, COSV53589441; called by muse, mutect2, varscan2
- NEU2 | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 54/215 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.855); catalogued as COSV52091700; called by muse, mutect2, varscan2
- NFATC2 | c.109G>C p.E37Q | Missense Mutation (SNP) | VAF 29/171 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as COSV101044071, COSV65353406; called by muse, mutect2, varscan2
- NLRC4 | c.2031C>G p.I677M | Missense Mutation (SNP) | VAF 33/162 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as COSV61591489; called by muse, mutect2, varscan2
- NLRP11 | c.529C>A p.Q177K | Missense Mutation (SNP) | VAF 46/183 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.401); catalogued as COSV64085816; called by muse, mutect2, varscan2
- NLRP12 | c.1483C>T p.L495F | Missense Mutation (SNP) | VAF 139/498 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60743904; called by muse, mutect2, varscan2
- NLRP13 | c.1572G>T p.K524N | Missense Mutation (SNP) | VAF 32/116 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.856); catalogued as COSV100738627, COSV61620108, COSV61620646; called by muse, mutect2, varscan2
- NLRP3 | c.318C>A p.C106* | Nonsense Mutation (SNP) | VAF 91/431 reads (21%) | catalogued as COSV60220518; called by muse, mutect2, varscan2
- NLRP9 | c.1696G>C p.E566Q | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.061); catalogued as COSV60460071; called by muse, mutect2, varscan2
- NOBOX | c.361C>A p.P121T | Missense Mutation (SNP) | VAF 11/16 reads (69%) | SIFT tolerated (0.08); PolyPhen benign (0.047); catalogued as COSV56192803; called by muse, mutect2, varscan2
- NOC4L | c.1018C>A p.H340N | Missense Mutation (SNP) | VAF 52/180 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV57957323; called by muse, mutect2, varscan2
- NOMO1 | c.997G>T p.G333W | Missense Mutation (SNP) | VAF 132/249 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1358306425; called by muse, mutect2, varscan2
- NOSTRIN | c.493G>A p.E165K (on ENST00000317647 / NM_001039724.4; = p.E87K on NM_052946.3) | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.871); catalogued as COSV100473034, COSV58319402; called by muse, varscan2
- NPAS3 | c.2797G>C p.D933H (on ENST00000356141 / NM_001164749.2; = p.D901H on NM_022123.3) | Missense Mutation (SNP) | VAF 45/68 reads (66%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.927); catalogued as COSV60823147; called by muse, mutect2, varscan2
- NPAS4 | c.2129T>C p.V710A | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT tolerated (0.09); PolyPhen benign (0.039); catalogued as COSV60648983; called by muse, mutect2, varscan2
- NPSR1 | c.1118G>A p.W373* | Nonsense Mutation (SNP) | VAF 35/120 reads (29%) | catalogued as COSV63103023; called by muse, mutect2, varscan2
- NPY2R | c.1013C>T p.S338L | Missense Mutation (SNP) | VAF 39/182 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs201907812, COSV61529792; called by muse, mutect2, varscan2
- NRAP | c.901G>A p.E301K | Missense Mutation (SNP) | VAF 45/131 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.14); catalogued as COSV63488677; called by muse, mutect2, varscan2
- NT5C2 | c.22C>T p.R8W | Missense Mutation (SNP) | VAF 49/170 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.642); catalogued as rs762409585, COSV58414599; called by muse, mutect2, varscan2
- NTNG1 | c.1315G>A p.E439K | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.119); catalogued as rs755713976, COSV64267813; called by muse, mutect2, varscan2
- NTRK3 | c.1987A>T p.I663F | Missense Mutation (SNP) | VAF 83/224 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62296630; called by muse, mutect2, varscan2
- NTRK3 | c.1821del p.C607Wfs*14 | Frame Shift Del (DEL) | VAF 64/205 reads (31%) | catalogued as COSV62299204; called by mutect2, pindel, varscan2
- NUDT1 | c.143G>A p.R48Q (on ENST00000397048 / NM_198952.1; = p.R25Q on NM_002452.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.942); catalogued as rs200613809; called by muse, varscan2
- NUMA1 | c.1447G>T p.E483* | Nonsense Mutation (SNP) | VAF 35/123 reads (28%) | catalogued as COSV61183501; called by muse, mutect2, varscan2
- NUP210 | c.2041A>G p.N681D | Missense Mutation (SNP) | VAF 111/266 reads (42%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.45); catalogued as COSV54402837; called by muse, mutect2, varscan2
- NUP214 | c.3758A>T p.D1253V | Missense Mutation (SNP) | VAF 33/115 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV63907826; called by muse, mutect2, varscan2
- NXPH1 | c.384C>G p.I128M | Missense Mutation (SNP) | VAF 95/562 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV68311596, COSV68316743; called by muse, mutect2, varscan2
- OBSCN | c.4972A>T p.T1658S | Missense Mutation (SNP) | VAF 203/419 reads (48%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.796); catalogued as COSV52744700; called by muse, mutect2, varscan2
- OBSCN | c.5296G>C p.E1766Q | Missense Mutation (SNP) | VAF 34/169 reads (20%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.721); catalogued as COSV52744958; called by muse, mutect2, varscan2
- OCA2 | c.2076G>T p.M692I | Missense Mutation (SNP) | VAF 65/124 reads (52%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.744); catalogued as COSV62339321; called by muse, mutect2, varscan2
- OLFML3 | c.1120A>T p.S374C | Missense Mutation (SNP) | VAF 50/186 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV57434698; called by muse, mutect2, varscan2
- OLIG1 | c.725C>A p.P242H | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as rs773680494, COSV60737614; called by muse, mutect2, varscan2
- OR10A2 | c.855G>T p.K285N | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV56298756; called by muse, mutect2, varscan2
- OR10K2 | c.93C>A p.F31L | Missense Mutation (SNP) | VAF 68/273 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV59220492, COSV59220991; called by muse, mutect2, varscan2
- OR10W1 | c.718C>A p.L240M | Missense Mutation (SNP) | VAF 35/129 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV67720219; called by muse, mutect2, varscan2
- OR14A16 | c.380C>T p.P127L | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as rs367660073; called by muse, varscan2
- OR14A16 | c.323C>A p.A108E | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.449); catalogued as COSV100713878, COSV62926178; called by muse, varscan2
- OR1A1 | c.566G>T p.C189F | Missense Mutation (SNP) | VAF 95/143 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58403187; called by muse, mutect2, varscan2
- OR1K1 | c.911C>A p.A304D | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as rs770069928, COSV52956194, COSV99474390; called by muse, varscan2
- OR2AG1 | c.210C>A p.D70E | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56625473; called by muse, mutect2, varscan2
- OR2AG1 | c.374C>T p.A125V | Missense Mutation (SNP) | VAF 47/112 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56625481; called by muse, mutect2, varscan2
- OR2G6 | c.335G>T p.C112F | Missense Mutation (SNP) | VAF 43/191 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58573773; called by muse, mutect2, varscan2
- OR2T1 | c.585G>T p.E195D | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.957); catalogued as COSV63541311; called by muse, mutect2, varscan2
- OR2T10 | c.766A>G p.I256V | Missense Mutation (SNP) | VAF 41/154 reads (27%) | SIFT tolerated (0.4); PolyPhen benign (0.074); catalogued as rs1404780177, COSV57896145; called by muse, mutect2, varscan2
- OR2T2 | c.73C>T p.P25S | Missense Mutation (SNP) | VAF 107/919 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as rs1024191710, COSV61617691, COSV61617841; called by muse, mutect2, varscan2
- OR2T4 | c.854G>T p.G285V | Missense Mutation (SNP) | VAF 259/472 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63543406; called by muse, mutect2, varscan2
- OR2T6 | c.492G>T p.M164I | Missense Mutation (SNP) | VAF 42/209 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.58); catalogued as COSV63215770; called by muse, mutect2, varscan2
- OR4A47 | c.664T>A p.S222T | Missense Mutation (SNP) | VAF 87/181 reads (48%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.143); catalogued as rs763200828, COSV71445024; called by muse, mutect2, varscan2
- OR4C6 | c.674C>A p.S225Y | Missense Mutation (SNP) | VAF 54/225 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.934); catalogued as COSV58602612; called by muse, mutect2, varscan2
- OR4E2 | c.932C>G p.S311* | Nonsense Mutation (SNP) | VAF 35/225 reads (16%) | catalogued as COSV57731425; called by muse, mutect2, varscan2
- OR4F6 | c.555C>G p.I185M | Missense Mutation (SNP) | VAF 59/201 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.345); catalogued as rs1367820734, COSV61026340; called by muse, mutect2, varscan2
- OR4K1 | c.722C>A p.T241N | Missense Mutation (SNP) | VAF 154/181 reads (85%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as COSV53458924; called by muse, mutect2, varscan2
- OR4Q3 | c.280T>C p.F94L | Missense Mutation (SNP) | VAF 71/117 reads (61%) | SIFT tolerated (0.72); PolyPhen benign (0.028); catalogued as COSV59177411; called by muse, mutect2, varscan2
- OR51G2 | c.476C>A p.A159E | Missense Mutation (SNP) | VAF 64/133 reads (48%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.545); catalogued as COSV58991937; called by muse, mutect2, varscan2
- OR51V1 | c.732C>G p.C244W | Missense Mutation (SNP) | VAF 52/128 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58314233; called by muse, mutect2, varscan2
- OR52B2 | c.874A>G p.I292V | Missense Mutation (SNP) | VAF 156/345 reads (45%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.51); catalogued as COSV73209224; called by muse, mutect2, varscan2
- OR52B4 | c.323C>G p.S108C | Missense Mutation (SNP) | VAF 89/309 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV68768612; called by muse, mutect2, varscan2
- OR52E8 | c.7G>A p.G3R | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as COSV66205006; called by muse, mutect2, varscan2
- OR5K3 | c.322G>A p.E108K | Missense Mutation (SNP) | VAF 37/300 reads (12%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.521); catalogued as COSV67349725, COSV67350008; called by muse, mutect2, varscan2
- OR6C1 | c.812G>A p.G271E | Missense Mutation (SNP) | VAF 56/263 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.25); catalogued as rs1442752654, COSV65572655; called by muse, mutect2, varscan2
- OR6K6 | c.324G>C p.K108N (on ENST00000368144; = p.K84N on NM_001005184.1) | Missense Mutation (SNP) | VAF 31/145 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.924); catalogued as COSV63743655, COSV63743868; called by muse, mutect2, varscan2
- OTOG | c.1892G>T p.R631L | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.131); catalogued as COSV68036241; called by muse, mutect2, varscan2
- OVCH1 | c.2188G>T p.E730* | Nonsense Mutation (SNP) | VAF 64/192 reads (33%) | catalogued as COSV58959896; called by muse, mutect2, varscan2
- OVOL1 | c.265C>T p.H89Y | Missense Mutation (SNP) | VAF 43/101 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs375344180; called by muse, mutect2, varscan2
- OVOL2 | c.552C>A p.F184L | Missense Mutation (SNP) | VAF 43/110 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53859596; called by muse, mutect2, varscan2
- PABPC4L | c.769G>T p.G257W | Missense Mutation (SNP) | VAF 44/130 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69929036; called by muse, mutect2, varscan2
- PACSIN3 | c.713G>T p.R238L | Missense Mutation (SNP) | VAF 63/129 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54065284; called by muse, mutect2, varscan2
- PAPPA | c.2131C>A p.H711N | Missense Mutation (SNP) | VAF 45/123 reads (37%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV100074659, COSV60277947; called by muse, mutect2, varscan2
- PAPPA2 | c.2810T>C p.L937P | Missense Mutation (SNP) | VAF 29/142 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV62791343; called by muse, mutect2, varscan2
- PAX4 | c.752C>T p.P251L | Missense Mutation (SNP) | VAF 133/186 reads (72%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as COSV58387582; called by muse, mutect2, varscan2
- PCDH10 | c.2216G>T p.R739L | Missense Mutation (SNP) | VAF 111/174 reads (64%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV52088140, COSV52106202; called by muse, varscan2
- PCDH12 | c.3058G>T p.D1020Y | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as rs1358467489, COSV51519509; called by muse, mutect2, varscan2
- PCDH15 | c.5791G>T p.E1931* | Nonsense Mutation (SNP) | VAF 32/90 reads (36%) | catalogued as COSV57267062; called by muse, mutect2, varscan2
- PCDH15 | c.2116G>T p.V706L | Missense Mutation (SNP) | VAF 61/216 reads (28%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.932); catalogued as COSV57267086; called by muse, mutect2, varscan2
- PCDH15 | c.1930G>T p.E644* | Nonsense Mutation (SNP) | VAF 42/175 reads (24%) | catalogued as COSV57267096, COSV57362650; called by muse, mutect2, varscan2
- PCDH8 | c.2356del p.A786Pfs*151 | Frame Shift Del (DEL) | VAF 43/80 reads (54%) | catalogued as rs770663005, COSV100131664; called by mutect2, pindel, varscan2
- PCDH9 | c.3359G>A p.R1120Q (on ENST00000377865 / NM_203487.3; = p.R1086Q on NM_020403.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/101 reads (44%) | SIFT tolerated (0.4); PolyPhen benign (0.011); catalogued as rs755054889, COSV60530796; called by muse, varscan2
- PCDHAC1 | c.1636G>A p.V546I | Missense Mutation (SNP) | VAF 65/178 reads (37%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.488); catalogued as COSV53838362; called by muse, mutect2, varscan2
- PCDHB12 | c.1072G>T p.E358* | Nonsense Mutation (SNP) | VAF 91/228 reads (40%) | catalogued as COSV53393454; called by muse, mutect2, varscan2
- PCDHB14 | c.851C>A p.A284E | Missense Mutation (SNP) | VAF 66/148 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.71); catalogued as rs782806290, COSV53386669; called by muse, mutect2, varscan2
- PCDHB2 | c.1296G>T p.R432S | Missense Mutation (SNP) | VAF 268/720 reads (37%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.513); catalogued as COSV50564507; called by muse, varscan2
- PCDHB3 | c.1229A>G p.D410G | Missense Mutation (SNP) | VAF 48/272 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV50564531; called by muse, mutect2
- PCDHB8 | c.1037C>A p.P346Q | Missense Mutation (SNP) | VAF 160/988 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV50754717; called by muse, varscan2
- PCDHB8 | c.1052C>T p.S351F | Missense Mutation (SNP) | VAF 132/1090 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.928); catalogued as rs868955896, COSV50754722, COSV50793442; called by muse, varscan2
- PCDHGA10 | c.2246G>T p.G749V | Missense Mutation (SNP) | VAF 237/587 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.652); catalogued as COSV53904791; called by muse, mutect2, varscan2
- PCDHGA12 | c.1192T>G p.Y398D | Missense Mutation (SNP) | VAF 48/146 reads (33%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.03); catalogued as COSV52744636; called by muse, mutect2, varscan2
- PCDHGA12 | c.1193A>T p.Y398F | Missense Mutation (SNP) | VAF 46/140 reads (33%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.012); catalogued as COSV52744662; called by muse, mutect2, varscan2
- PCDHGA2 | c.73del p.E25Rfs*21 | Frame Shift Del (DEL) | VAF 49/128 reads (38%) | catalogued as COSV99530476, COSV99546985; called by mutect2, pindel, varscan2
- PCDHGA2 | c.2221G>T p.V741L | Missense Mutation (SNP) | VAF 210/589 reads (36%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.02); catalogued as COSV53904688; called by muse, mutect2, varscan2
- PCDHGA4 | c.412G>T p.E138* | Nonsense Mutation (SNP) | VAF 75/227 reads (33%) | catalogued as COSV53904696; called by muse, mutect2, varscan2
- PCDHGA4 | c.1423G>C p.D475H | Missense Mutation (SNP) | VAF 41/236 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53904709; called by muse, mutect2, varscan2
- PCDHGA5 | c.1477G>A p.E493K | Missense Mutation (SNP) | VAF 33/158 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.114); catalogued as COSV53904737, COSV54061565; called by muse, mutect2, varscan2
- PCDHGB2 | c.1611G>T p.Q537H | Missense Mutation (SNP) | VAF 138/361 reads (38%) | SIFT tolerated (0.49); PolyPhen benign (0.019); catalogued as COSV53904726; called by muse, mutect2, varscan2
- PCDHGB7 | c.1219G>A p.D407N | Missense Mutation (SNP) | VAF 66/171 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.461); catalogued as COSV53904797; called by muse, mutect2, varscan2
- PCNT | c.2524G>C p.E842Q | Missense Mutation (SNP) | VAF 22/36 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV64025049, COSV64025882, COSV64029451; called by muse, mutect2, varscan2
- PCNX1 | c.4873G>T p.E1625* | Nonsense Mutation (SNP) | VAF 52/71 reads (73%) | catalogued as COSV53089849; called by muse, mutect2, varscan2
- PDCD2 | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 20/135 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.723); catalogued as COSV51341018; called by muse, mutect2, varscan2
- PDE1C | c.443C>T p.S148L | Missense Mutation (SNP) | VAF 27/123 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.313); catalogued as COSV58504163; called by muse, mutect2, varscan2
- PDE5A | c.2348C>T p.A783V | Missense Mutation (SNP) | VAF 38/128 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV53345795; called by muse, mutect2, varscan2
- PDE6B | c.1336G>C p.D446H | Missense Mutation (SNP) | VAF 44/170 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as COSV55324099; called by muse, mutect2, varscan2
- PDE8A | c.166C>T p.R56C | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.18); catalogued as rs1289041095, COSV59634980; called by muse, varscan2
- PDS5B | c.277C>A p.P93T | Missense Mutation (SNP) | VAF 70/324 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59723736; called by muse, mutect2, varscan2
- PGBD1 | c.1045C>G p.R349G | Missense Mutation (SNP) | VAF 45/178 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV52551492, COSV52552799; called by muse, mutect2, varscan2
- PGK2 | c.641G>T p.G214V | Missense Mutation (SNP) | VAF 139/341 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59162883; called by muse, mutect2, varscan2
- PHACTR1 | c.1117G>A p.D373N | Missense Mutation (SNP) | VAF 105/285 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as COSV60660125; called by muse, mutect2, varscan2
- PHACTR3 | c.353A>G p.E118G | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.196); catalogued as COSV63025472; called by muse, mutect2, varscan2
- PHC3 | c.1181A>G p.Q394R (on ENST00000494943 / NM_001308116.2; = p.Q406R on NM_024947.4) | Missense Mutation (SNP) | VAF 36/361 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.838); catalogued as COSV71948388; called by muse, mutect2, varscan2
- PHF2 | c.97A>G p.S33G | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.89); catalogued as COSV63681278; called by muse, mutect2, varscan2
- PHLDB1 | c.3018G>T p.K1006N | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as rs200360488, COSV61876589, COSV61878474; called by muse, mutect2, varscan2
- PHLDB2 | c.3535G>T p.D1179Y (on ENST00000393925 / NM_001134439.2; = p.D1136Y on NM_145753.2) | Missense Mutation (SNP) | VAF 60/154 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67308453; called by muse, mutect2, varscan2
- PHLDB3 | c.1514G>T p.G505V | Missense Mutation (SNP) | VAF 24/144 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0.235); catalogued as COSV52667918; called by muse, varscan2
- PHLPP1 | c.4651G>A p.E1551K | Missense Mutation (SNP) | VAF 46/202 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV53023165; called by muse, varscan2
- PHLPP1 | c.4753C>G p.Q1585E | Missense Mutation (SNP) | VAF 39/160 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV53023196; called by muse, varscan2
- PHOSPHO2 | c.523G>T p.V175F | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.029); catalogued as COSV55865816; called by muse, mutect2, varscan2
- PIAS4 | c.554G>A p.G185E | Missense Mutation (SNP) | VAF 53/173 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV53678321; called by muse, mutect2, varscan2
- PIK3C2G | c.4219G>C p.E1407Q (on ENST00000676171; = p.E1366Q on NM_004570.5) | Missense Mutation (SNP) | VAF 42/138 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV56798056, COSV56815703; called by muse, mutect2, varscan2
- PIK3CG | c.814C>A p.L272M | Missense Mutation (SNP) | VAF 227/292 reads (78%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV63245802, COSV63248844; called by muse, mutect2, varscan2
- PIK3R2 | c.2170C>T p.P724S | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.099); catalogued as COSV55846862; called by muse, mutect2, varscan2
- PIK3R6 | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.858); catalogued as COSV61003813; called by muse, mutect2, varscan2
- PIN1 | c.62G>A p.R21Q | Missense Mutation (SNP) | VAF 77/208 reads (37%) | SIFT tolerated (0.66); PolyPhen benign (0.005); catalogued as rs750534329; called by muse, mutect2, varscan2
1,184 further variants in this file (548 protein-altering or splice-affecting, 390 silent, 246 other) are not listed here.
